Somatic mutation profile of tumor specimen HCM-CSHL-0806-C54-01A (aliquot HCM-CSHL-0806-C54-01A-11D-A881-36) from HCMI case HCM-CSHL-0806-C54, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous surface papillary carcinoma; Tissue or organ of origin: Endometrium; AJCC pathologic stage: Stage IIIC1; FIGO stage: Stage IIIC1.
Specimen HCM-CSHL-0806-C54-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9a8c75b8-9a9a-423d-9760-44333d48553d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0806-C54-11A (Solid Tissue Normal), aliquot HCM-CSHL-0806-C54-11A-01D-A881-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1acef5f0-a35f-4fc2-ab4e-c73d7c6e364d

The open-access MAF lists 1,129 somatic variants for this specimen: 831 protein-altering or splice-affecting, 259 silent, 39 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 620, Silent 259, Frame Shift Del 129, Nonsense Mutation 44, Frame Shift Ins 24, Intron 23, 3'UTR 6, 5'Flank 4, Splice Region 4, Splice Site 3, 5'UTR 3, In Frame Ins 2.

Variants (750 of 1,129; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALPL | c.1171del p.R391Vfs*12 | Frame Shift Del (DEL) | VAF 54/499 reads (11%) | catalogued as rs751404811, CM045926, CM138787; ClinVar: likely pathogenic; called by mutect2, pindel
- ARID1A | c.5965C>T p.R1989* | Nonsense Mutation (SNP) | VAF 185/498 reads (37%) | hotspot (GDC flag); catalogued as rs879255270, CM1311944, COSV61370535; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DDX3X | c.1123C>T p.R375C (on ENST00000399959; = p.R376C on NM_001356.5) | Missense Mutation (SNP) | VAF 16/570 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs796052231, CM158018, COSV67863865, COSV67864092; ClinVar: pathogenic; called by muse, mutect2
- LRPPRC | c.2966G>A p.R989H | Missense Mutation (SNP) | VAF 36/432 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as rs774857058, COSV53236937; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2
- OPA1 | c.868C>T p.R290* (on ENST00000361510 / NM_130837.3; = p.R235* on NM_015560.3) | Nonsense Mutation (SNP) | VAF 31/189 reads (16%) | catalogued as rs761743852, CM136994; ClinVar: pathogenic; called by muse, varscan2
- PIK3CA | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 62/328 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs886042002, CM162636, COSV55873442, COSV55926654, COSV55949642; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1634A>C p.E545A | Missense Mutation (SNP) | VAF 97/281 reads (35%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as rs121913274, CM130273, COSV55873209, COSV55873220, COSV55892885; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- RRAS2 | c.215A>T p.Q72L | Missense Mutation (SNP) | VAF 213/294 reads (72%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as rs113954997, COSV56329169; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A2M | c.337G>T p.E113* | Nonsense Mutation (SNP) | VAF 28/574 reads (5%) | catalogued as COSV59388760, COSV59389701; called by muse, mutect2
- ABCC12 | c.4049C>T p.A1350V | Missense Mutation (SNP) | VAF 90/400 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.184); catalogued as rs767290200; called by muse, varscan2
- ABHD14B | c.314C>T p.P105L | Missense Mutation (SNP) | VAF 79/598 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.221); catalogued as rs543830840; called by muse, mutect2, varscan2
- ACSL6 | c.1664G>A p.R555Q (on ENST00000379240; = p.R580Q on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/378 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs1489614135, COSV57303962, COSV99734756; called by muse, mutect2
- ACSS1 | c.520G>A p.V174M | Missense Mutation (SNP) | VAF 71/738 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.094); catalogued as rs200650895, COSV99067805; called by muse, mutect2
- ACTN3 | c.1078C>T p.R360W | Missense Mutation (SNP) | VAF 64/449 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs371613741; called by muse, varscan2
- ACTRT2 | c.397G>A p.V133M | Missense Mutation (SNP) | VAF 89/724 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.766); catalogued as rs150794947, COSV65760423; called by muse, mutect2, varscan2
- ADAMTS16 | c.2802dup p.N935Efs*27 | Frame Shift Ins (INS) | VAF 42/363 reads (12%) | catalogued as rs1392687502; called by mutect2, pindel, varscan2
- ADAMTS17 | c.994G>A p.D332N | Missense Mutation (SNP) | VAF 54/537 reads (10%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.99); catalogued as rs746864724, COSV99171576; called by muse, mutect2, varscan2
- ADAMTS5 | c.485G>A p.R162H | Missense Mutation (SNP) | VAF 71/666 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.101); catalogued as COSV53178518; called by muse, mutect2, varscan2
- ADGRA1 | c.827C>T p.A276V | Missense Mutation (SNP) | VAF 94/799 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs939795530; called by muse, mutect2, varscan2
- ADGRG4 | c.8874del p.F2958Lfs*6 | Frame Shift Del (DEL) | VAF 99/776 reads (13%) | catalogued as rs771931957; called by mutect2, pindel, varscan2
- AGAP5 | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 26/444 reads (6%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.025); catalogued as rs915210056, COSV100932654; called by muse, mutect2
- AGBL3 | c.2474G>T p.R825M | Missense Mutation (SNP) | VAF 41/477 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.238); catalogued as COSV71379628; called by muse, mutect2
- AKNA | c.1975A>G p.I659V | Missense Mutation (SNP) | VAF 57/644 reads (9%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as rs758036540; called by muse, mutect2
- ANKHD1-EIF4EBP3 | c.4594del p.R1532Gfs*5 | Frame Shift Del (DEL) | VAF 45/418 reads (11%) | catalogued as COSV51845823; called by mutect2, pindel, varscan2
- ANKRD35 | c.2611C>T p.R871W | Missense Mutation (SNP) | VAF 56/636 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs781878029; called by muse, mutect2
- ANKS4B | c.67C>T p.R23* | Nonsense Mutation (SNP) | VAF 80/474 reads (17%) | catalogued as rs763113188; called by muse, mutect2, varscan2
- AOPEP | c.1201C>T p.R401W | Missense Mutation (SNP) | VAF 66/614 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754444042, COSV52921607; called by muse, mutect2
- AP1B1 | c.1334G>A p.R445Q | Missense Mutation (SNP) | VAF 190/552 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs376948907; called by muse, varscan2
- APBA1 | c.157C>T p.R53C | Missense Mutation (SNP) | VAF 80/923 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs564159274, COSV55232051; called by muse, mutect2
- APBA3 | c.898A>G p.I300V | Missense Mutation (SNP) | VAF 38/848 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.387); catalogued as rs1481938368; called by muse, mutect2
- ARAF | c.17G>C p.G6A | Missense Mutation (SNP) | VAF 48/555 reads (9%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV51695585; called by muse, mutect2
- ARNT | c.1154G>A p.G385D | Missense Mutation (SNP) | VAF 47/436 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs764851308; called by muse, mutect2, varscan2
- ASB16 | c.737C>T p.A246V | Missense Mutation (SNP) | VAF 32/854 reads (4%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.965); catalogued as rs1373310670; called by muse, mutect2
- ASGR1 | c.428C>T p.A143V | Missense Mutation (SNP) | VAF 88/523 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0.01); catalogued as rs1340268632, COSV52648428; called by muse, mutect2, varscan2
- ASTN2 | c.2206G>A p.G736S (on ENST00000313400 / NM_001365069.1; = p.G685S on NM_014010.5) | Missense Mutation (SNP) | VAF 40/334 reads (12%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as rs149350423; called by muse, mutect2, varscan2
- ATM | c.1021G>A p.V341I | Missense Mutation (SNP) | VAF 48/287 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.815); catalogued as rs200601781, COSV99592134; ClinVar: not provided / likely benign / uncertain significance; called by muse, mutect2, varscan2
- ATP2A1 | c.1712del p.P571Rfs*21 | Frame Shift Del (DEL) | VAF 57/555 reads (10%) | catalogued as rs772363145; called by mutect2, pindel, varscan2
- ATRX | c.5216G>A p.R1739Q | Missense Mutation (SNP) | VAF 16/363 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.623); catalogued as COSV64874516; called by muse, mutect2
- B3GAT2 | c.359C>T p.A120V | Missense Mutation (SNP) | VAF 33/652 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs1458696838; called by muse, mutect2
- B3GNT6 | c.974G>A p.G325D | Missense Mutation (SNP) | VAF 77/892 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.253); catalogued as rs1190991724; called by muse, mutect2
- B3GNT7 | c.380C>T p.P127L | Missense Mutation (SNP) | VAF 87/639 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs780328214; called by muse, mutect2, varscan2
- B4GALNT3 | c.860C>T p.T287M | Missense Mutation (SNP) | VAF 40/365 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs142628932, COSV104383590; called by muse, mutect2, varscan2
- BAIAP2L1 | c.1307del p.P436Hfs*60 | Frame Shift Del (DEL) | VAF 58/481 reads (12%) | catalogued as rs1405664842, COSV50055281; called by mutect2, pindel, varscan2
- BAIAP3 | c.2873dup p.H959Pfs*66 | Frame Shift Ins (INS) | VAF 66/393 reads (17%) | catalogued as rs1313326417; called by mutect2, pindel, varscan2
- BAZ1B | c.4360C>T p.R1454C | Missense Mutation (SNP) | VAF 63/543 reads (12%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs782582882; called by muse, mutect2, varscan2
- BBS4 | c.134G>A p.R45Q | Missense Mutation (SNP) | VAF 27/278 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.086); catalogued as rs1050164962, COSV51437450; ClinVar: uncertain significance; called by muse, mutect2
- BBS9 | c.808dup p.C270Lfs*3 | Frame Shift Ins (INS) | VAF 58/359 reads (16%) | catalogued as rs1288376188; called by mutect2, varscan2
- BDH1 | c.119C>T p.P40L | Missense Mutation (SNP) | VAF 20/680 reads (3%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV100827162, COSV64018654; called by muse, mutect2
- BRI3BP | c.341G>A p.S114N | Missense Mutation (SNP) | VAF 44/524 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.027); catalogued as COSV58297672; called by muse, mutect2
- BRINP2 | c.628C>T p.R210* | Nonsense Mutation (SNP) | VAF 47/500 reads (9%) | catalogued as rs138839091, COSV64179456; called by muse, mutect2
- BRPF1 | c.85C>T p.R29* | Nonsense Mutation (SNP) | VAF 62/417 reads (15%) | catalogued as COSV57404653; called by muse, mutect2, varscan2
- BYSL | c.1102C>T p.R368W | Missense Mutation (SNP) | VAF 53/503 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs548151085; called by muse, mutect2, varscan2
- C1QTNF12 | c.853del p.A285Pfs*38 | Frame Shift Del (DEL) | VAF 159/805 reads (20%) | catalogued as rs764140303; called by mutect2, pindel, varscan2
- C5 | c.628del p.S210Qfs*41 | Frame Shift Del (DEL) | VAF 45/321 reads (14%) | catalogued as COSV56326725; called by mutect2, pindel, varscan2
- C5orf38 | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 154/758 reads (20%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.268); catalogued as rs1231627026; called by muse, varscan2
- CACNA1D | c.5708G>A p.R1903Q (on ENST00000350061 / NM_001128840.3; = p.R1923Q on NM_000720.4) | Missense Mutation (SNP) | VAF 47/638 reads (7%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as rs373251538; ClinVar: uncertain significance; called by muse, mutect2
- CADM2 | c.199G>T p.D67Y (on ENST00000407528 / NM_001167674.2; = p.D69Y on NM_153184.4) | Missense Mutation (SNP) | VAF 35/418 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV101053194; called by muse, mutect2
- CAND2 | c.2286G>T p.Q762H (on ENST00000456430 / NM_001162499.2; = p.Q669H on NM_012298.3) | Missense Mutation (SNP) | VAF 70/704 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.719); catalogued as COSV55986345; called by muse, mutect2
- CAPN5 | c.673G>A p.A225T (on ENST00000456580; = p.A185T on NM_004055.5) | Missense Mutation (SNP) | VAF 75/547 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1160895416, COSV53690892; called by muse, mutect2, varscan2
- CASZ1 | c.3320C>T p.P1107L | Missense Mutation (SNP) | VAF 98/831 reads (12%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs771060379, COSV100681321, COSV100681755; called by muse, mutect2, varscan2
- CCDC105 | c.553A>G p.R185G | Missense Mutation (SNP) | VAF 16/453 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs866516263; called by muse, mutect2
- CCDC110 | c.1774del p.T592Hfs*5 | Frame Shift Del (DEL) | VAF 48/292 reads (16%) | catalogued as rs368765497; called by mutect2, pindel, varscan2
- CCDC181 | c.1078C>T p.R360* | Nonsense Mutation (SNP) | VAF 76/244 reads (31%) | catalogued as rs1375457947, COSV63156352; called by muse, mutect2, varscan2
- CCDC22 | c.1345C>T p.R449W | Missense Mutation (SNP) | VAF 26/598 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as rs781929389, COSV66050894; called by muse, mutect2
- CCDC82 | c.886G>A p.D296N | Missense Mutation (SNP) | VAF 88/398 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs146108139; called by muse, mutect2, varscan2
- CCN4 | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 84/678 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as rs753495859, COSV51531014, COSV99137013; called by muse, mutect2, varscan2
- CCNF | c.1501G>A p.A501T | Missense Mutation (SNP) | VAF 19/493 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.129); catalogued as rs1428900926, COSV53539584; called by muse, mutect2
- CD70 | c.575G>A p.R192H | Missense Mutation (SNP) | VAF 28/392 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs770306833; called by muse, mutect2
- CDHR1 | c.2477C>T p.P826L | Missense Mutation (SNP) | VAF 77/696 reads (11%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs1173189717; called by muse, mutect2, varscan2
- CEACAM6 | c.712G>A p.D238N | Missense Mutation (SNP) | VAF 41/267 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.222); catalogued as COSV99555397; called by muse, mutect2, varscan2
- CELSR3 | c.3829G>A p.V1277M | Missense Mutation (SNP) | VAF 71/574 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1444797621, CM142333, COSV50849963; called by muse, mutect2, varscan2
- CELSR3 | c.3695G>A p.R1232Q | Missense Mutation (SNP) | VAF 169/438 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.27); catalogued as rs758323399, COSV99373351; called by muse, varscan2
- CENPQ | c.440G>A p.R147Q | Missense Mutation (SNP) | VAF 45/223 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs367615344, COSV59920891; called by muse, mutect2, varscan2
- CEP131 | c.1208C>T p.A403V | Missense Mutation (SNP) | VAF 62/688 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.018); catalogued as rs576448333; called by muse, mutect2
- CHRNA10 | c.424G>A p.V142M | Missense Mutation (SNP) | VAF 113/827 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.531); catalogued as COSV51705539; called by muse, mutect2, varscan2
- CLASP1 | c.3539G>A p.S1180N | Missense Mutation (SNP) | VAF 40/417 reads (10%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.889); catalogued as COSV55322269; called by muse, mutect2
- CLIC3 | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 46/744 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65406521; called by muse, mutect2
- CNGA4 | c.748G>A p.D250N | Missense Mutation (SNP) | VAF 154/661 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as COSV66006361; called by muse, mutect2, varscan2
- CNNM1 | c.1843C>T p.R615C | Missense Mutation (SNP) | VAF 38/398 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs1045666486; called by muse, mutect2
- COL4A4 | c.4390G>A p.G1464S | Missense Mutation (SNP) | VAF 63/839 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs372558522; called by muse, mutect2
- CSNK1D | c.896G>A p.R299Q | Missense Mutation (SNP) | VAF 27/662 reads (4%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.005); catalogued as rs866797018, COSV53922745; called by muse, mutect2
- CSPG5 | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 66/650 reads (10%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.022); catalogued as rs1162551428; called by muse, mutect2
- CTNND1 | c.920G>A p.R307Q | Missense Mutation (SNP) | VAF 64/450 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs371819372; called by muse, mutect2, varscan2
- CUL9 | c.2560G>A p.V854M | Missense Mutation (SNP) | VAF 39/400 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.765); catalogued as rs1278567798, COSV99335069; called by muse, mutect2, varscan2
- CXCR3 | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 34/1032 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.298); catalogued as rs913064075, COSV65462239; called by muse, mutect2
- CYP2F1 | c.1031C>T p.A344V | Missense Mutation (SNP) | VAF 77/719 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs761170962, COSV58527098; called by muse, mutect2, varscan2
- DACT2 | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 48/970 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs908568574; called by muse, mutect2
- DBF4 | c.74dup p.N25Kfs*11 | Frame Shift Ins (INS) | VAF 42/232 reads (18%) | catalogued as rs762918884; called by mutect2, varscan2
- DCAF1 | c.2809dup p.Q937Pfs*20 | Frame Shift Ins (INS) | VAF 105/482 reads (22%) | catalogued as rs782606429; called by mutect2, varscan2
- DCAF8L1 | c.512G>A p.R171H | Missense Mutation (SNP) | VAF 20/665 reads (3%) | SIFT tolerated (0.16); PolyPhen benign (0.018); catalogued as rs1368406319, COSV101491519; called by muse, mutect2
- DENND4C | c.3583G>A p.V1195I (on ENST00000434457 / NM_001330640.2; = p.V1146I on NM_017925.7) | Missense Mutation (SNP) | VAF 62/265 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs776596059, COSV100727537; called by muse, varscan2
- DHX38 | c.3556C>T p.R1186W | Missense Mutation (SNP) | VAF 66/376 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1021379081; called by muse, varscan2
- DIDO1 | c.6463G>A p.A2155T | Missense Mutation (SNP) | VAF 74/672 reads (11%) | SIFT tolerated (0.75); PolyPhen benign (0.005); catalogued as COSV56623162; called by muse, varscan2
- DLGAP4 | c.646G>A p.G216S | Missense Mutation (SNP) | VAF 138/703 reads (20%) | SIFT tolerated (0.98); PolyPhen benign (0.003); catalogued as rs202018894; called by muse, mutect2, varscan2
- DLL1 | c.1357G>A p.A453T | Missense Mutation (SNP) | VAF 76/1023 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.244); catalogued as rs763449437, COSV64536814; called by muse, mutect2
- DMBX1 | c.1093C>T p.R365W | Missense Mutation (SNP) | VAF 22/696 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1418825492; called by muse, mutect2
- DMTN | c.455C>T p.S152F | Missense Mutation (SNP) | VAF 40/394 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.44); catalogued as rs1464049702, COSV56113765, COSV56114644; called by muse, mutect2
- DNAH2 | c.2407A>G p.M803V | Missense Mutation (SNP) | VAF 34/546 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs1476766696; called by muse, mutect2
- DOCK8 | c.3044G>A p.R1015H | Missense Mutation (SNP) | VAF 58/532 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); catalogued as rs200494857, COSV101209984; called by muse, mutect2, varscan2
- DPEP3 | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 43/314 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.86); catalogued as rs755341288; called by muse, mutect2, varscan2
- DPYS | c.1017G>T p.K339N | Missense Mutation (SNP) | VAF 68/614 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV60912450; called by muse, mutect2, varscan2
- DYNC2H1 | c.5000T>C p.L1667P | Missense Mutation (SNP) | VAF 28/306 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100517068; called by muse, mutect2
- E2F1 | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 58/530 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as rs531113927, COSV55775380; called by muse, varscan2
- EEF2K | c.991C>T p.R331W | Missense Mutation (SNP) | VAF 91/530 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.28); catalogued as rs1427315364, COSV53786902; called by muse, mutect2, varscan2
- EFNA5 | c.316C>T p.H106Y | Missense Mutation (SNP) | VAF 57/555 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.471); catalogued as COSV100321242; called by muse, mutect2, varscan2
- EHBP1L1 | c.1755G>T p.Q585H | Missense Mutation (SNP) | VAF 26/536 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.121); catalogued as COSV58572932; called by muse, mutect2
- EMC1 | c.2155G>A p.V719I | Missense Mutation (SNP) | VAF 20/649 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as rs1052665530; called by muse, mutect2
- EOLA1 | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 118/951 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.702); catalogued as COSV63734040; called by muse, mutect2, varscan2
- EPHA3 | c.1928C>T p.P643L | Missense Mutation (SNP) | VAF 121/363 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs146728702; called by muse, mutect2, varscan2
- EPHB4 | c.1291C>T p.R431* | Nonsense Mutation (SNP) | VAF 36/266 reads (14%) | catalogued as rs779782731, COSV62268576; called by muse, mutect2, varscan2
- EPN2 | c.1408dup p.T470Nfs*19 | Frame Shift Ins (INS) | VAF 37/310 reads (12%) | catalogued as rs756461692; called by mutect2, varscan2
- ESS2 | c.1292C>T p.P431L | Missense Mutation (SNP) | VAF 149/693 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as rs756678975; called by muse, varscan2
- ETF1 | c.1296dup p.D433* | Frame Shift Ins (INS) | VAF 78/449 reads (17%) | catalogued as rs34007600; called by mutect2, pindel, varscan2
- EWSR1 | c.1687C>T p.R563C | Missense Mutation (SNP) | VAF 57/412 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs199957418, COSV58424345; called by muse, mutect2, varscan2
- FAAH | c.488C>T p.P163L | Missense Mutation (SNP) | VAF 66/612 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.067); catalogued as rs199748056, COSV54543545, COSV99680068; called by muse, mutect2
- FAM120C | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 42/902 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.153); catalogued as rs782085379; called by muse, mutect2
- FAM193A | c.2497del p.M833Wfs*23 | Frame Shift Del (DEL) | VAF 56/412 reads (14%) | catalogued as rs768952789; called by mutect2, pindel, varscan2
- FAM236C | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 102/299 reads (34%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1274426882; called by muse, mutect2, varscan2
- FAM83G | c.1889G>A p.R630Q | Missense Mutation (SNP) | VAF 90/723 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs759629345; called by muse, mutect2, varscan2
- FAT3 | c.6922C>A p.Q2308K | Missense Mutation (SNP) | VAF 152/421 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.069); catalogued as COSV53107155; called by muse, mutect2, varscan2
- FBLN7 | c.1172G>A p.R391Q | Missense Mutation (SNP) | VAF 281/738 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs199980872; called by muse, mutect2, varscan2
- FBXO17 | c.31C>T p.P11S | Missense Mutation (SNP) | VAF 34/705 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1016970456, COSV53068896; called by muse, mutect2
- FCHSD2 | c.619G>A p.A207T | Missense Mutation (SNP) | VAF 24/504 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.041); catalogued as rs963539344, COSV60808698, COSV60812764; called by muse, mutect2
- FGFRL1 | c.949G>T p.G317C | Missense Mutation (SNP) | VAF 170/832 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1461069330, COSV99294580; called by muse, varscan2
- FMNL3 | c.377G>A p.R126Q | Missense Mutation (SNP) | VAF 65/354 reads (18%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.661); catalogued as rs1444059344, COSV53301283; called by muse, mutect2, varscan2
- FNDC11 | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 95/717 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs143932195; called by muse, mutect2, varscan2
- FNDC4 | c.30del p.S11Afs*17 | Frame Shift Del (DEL) | VAF 68/532 reads (13%) | catalogued as rs771665646, COSV99253963; called by mutect2, varscan2
- FOXD2 | c.268del p.A90Rfs*37 | Frame Shift Del (DEL) | VAF 32/280 reads (11%) | catalogued as rs1204362076; called by pindel, varscan2
- FZD7 | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 77/633 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as COSV53809332, COSV53809789; called by muse, mutect2, varscan2
- GAK | c.1480G>A p.A494T | Missense Mutation (SNP) | VAF 90/393 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0.048); catalogued as rs148765045; called by muse, mutect2, varscan2
- GAL3ST1 | c.842G>A p.R281H | Missense Mutation (SNP) | VAF 68/684 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1391538706, COSV58891870; called by muse, mutect2
- GBA2 | c.2446C>T p.Q816* | Nonsense Mutation (SNP) | VAF 74/612 reads (12%) | catalogued as COSV62305635; called by muse, mutect2, varscan2
- GGTLC1 | c.279del p.S94Hfs*58 | Frame Shift Del (DEL) | VAF 67/353 reads (19%) | catalogued as rs753146433; called by mutect2, pindel, varscan2
- GOLGA6B | c.1593G>A p.T531= | Splice Region (SNP) | VAF 43/336 reads (13%) | catalogued as rs770908530; called by muse, mutect2, varscan2
- GOLGA6L2 | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 86/278 reads (31%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.553); catalogued as rs566940056, COSV61475075; called by muse, varscan2
- GPC4 | c.499C>T p.R167C | Missense Mutation (SNP) | VAF 77/748 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs1274379465; called by muse, varscan2
- GPR108 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 111/434 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.775); catalogued as rs1030041616; called by muse, mutect2, varscan2
- GPR35 | c.412G>A p.A138T | Missense Mutation (SNP) | VAF 112/930 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.125); catalogued as rs376265458, COSV60576980; called by muse, mutect2, varscan2
- GPR6 | c.995G>A p.R332H | Missense Mutation (SNP) | VAF 36/732 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51572663; called by muse, mutect2
- GRHL2 | c.1468C>A p.L490M | Missense Mutation (SNP) | VAF 38/490 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.41); catalogued as rs756960152; called by muse, mutect2
- GRIK4 | c.1809del p.F604Sfs*27 | Frame Shift Del (DEL) | VAF 64/690 reads (9%) | catalogued as COSV70801839; called by mutect2, pindel
- GRTP1 | c.662G>A p.R221H | Missense Mutation (SNP) | VAF 157/780 reads (20%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.506); catalogued as rs373647513; called by muse, mutect2, varscan2
- GSE1 | c.1228C>T p.P410S | Missense Mutation (SNP) | VAF 176/796 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV53674512; called by muse, varscan2
- GSG1L2 | c.400G>A p.V134I | Missense Mutation (SNP) | VAF 24/489 reads (5%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs1189366511; called by muse, mutect2
- HAPLN4 | c.1012C>T p.R338C | Missense Mutation (SNP) | VAF 39/962 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV52268431; called by muse, mutect2
- HELZ2 | c.1312C>T p.R438W | Missense Mutation (SNP) | VAF 150/708 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs771605417, COSV64409045; called by muse, varscan2
- HERC2 | c.10811G>A p.S3604N | Missense Mutation (SNP) | VAF 76/844 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.109); catalogued as rs1177546597; called by muse, mutect2
- HIC2 | c.1706G>A p.R569H | Missense Mutation (SNP) | VAF 86/692 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV68041787; called by muse, mutect2, varscan2
- HIVEP2 | c.3082C>T p.R1028* | Nonsense Mutation (SNP) | VAF 52/522 reads (10%) | catalogued as COSV50007394; called by muse, mutect2
- HLA-G | c.627del p.K210Rfs*4 | Frame Shift Del (DEL) | VAF 51/355 reads (14%) | catalogued as rs752829354, COSV64406835; called by mutect2, pindel, varscan2
- HOXB4 | c.722del p.P241Lfs*28 | Frame Shift Del (DEL) | VAF 46/440 reads (10%) | catalogued as rs1278368885, COSV60178238; called by pindel, varscan2
- HOXC12 | c.88C>T p.R30C | Missense Mutation (SNP) | VAF 36/716 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54534781; called by muse, mutect2
- HSDL1 | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 102/485 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.086); catalogued as rs146729333; called by muse, mutect2, varscan2
- HUWE1 | c.12020G>A p.R4007H | Missense Mutation (SNP) | VAF 145/446 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1556914313; called by muse, varscan2
- IFNG | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 103/345 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs755519988, COSV57491375; called by muse, mutect2, varscan2
- IGLL5 | c.118C>T p.R40C | Missense Mutation (SNP) | VAF 98/726 reads (13%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.062); catalogued as rs552347865, COSV73249620; called by muse, mutect2, varscan2
- IL10RA | c.302G>A p.R101Q | Missense Mutation (SNP) | VAF 116/552 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs372372851; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IL2RB | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 40/303 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV53427773; called by muse, mutect2, varscan2
- INTS1 | c.4500del p.L1501Sfs*28 | Frame Shift Del (DEL) | VAF 43/438 reads (10%) | catalogued as rs746857576; called by mutect2, pindel, varscan2
- IQCE | c.745C>T p.R249W | Missense Mutation (SNP) | VAF 16/312 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867032551, COSV58077124; called by muse, mutect2
- ITIH1 | c.398C>T p.A133V | Missense Mutation (SNP) | VAF 40/368 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV56254960, COSV99835078; called by muse, mutect2, varscan2
- JAG2 | c.584G>A p.R195H | Missense Mutation (SNP) | VAF 34/759 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1389623306; called by muse, mutect2
- JMY | c.403G>T p.G135W | Missense Mutation (SNP) | VAF 26/922 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.889); catalogued as rs1561284076; called by muse, mutect2
- KBTBD7 | c.1477C>T p.R493C | Missense Mutation (SNP) | VAF 72/364 reads (20%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); catalogued as COSV65266552; called by muse, varscan2
- KCNB2 | c.128del p.G43Afs*40 | Frame Shift Del (DEL) | VAF 55/573 reads (10%) | catalogued as COSV73053085; called by mutect2, pindel, varscan2
- KCNH3 | c.2404C>T p.R802W | Missense Mutation (SNP) | VAF 86/660 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as rs770591531, COSV57790171; called by muse, varscan2
- KCNH5 | c.11del p.G4Afs*37 | Frame Shift Del (DEL) | VAF 66/544 reads (12%) | catalogued as COSV59765016; called by mutect2, pindel, varscan2
- KCNV1 | c.1063G>A p.V355M | Missense Mutation (SNP) | VAF 60/321 reads (19%) | SIFT tolerated (0.91); PolyPhen probably damaging (0.998); catalogued as rs756504582, COSV52084851; called by muse, varscan2
- KCP | c.2739del p.D914Tfs*111 (on ENST00000620378; = p.D974Tfs*111 on NM_001366122.1) | Frame Shift Del (DEL) | VAF 66/670 reads (10%) | catalogued as rs778175457; called by mutect2, pindel
- KDM4D | c.1255C>T p.R419W | Missense Mutation (SNP) | VAF 124/559 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs374912184; called by muse, varscan2
- KIAA1109 | c.1559C>T p.T520M | Missense Mutation (SNP) | VAF 28/267 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs368386353; called by muse, mutect2, varscan2
- KIAA1217 | c.5207G>A p.R1736H | Missense Mutation (SNP) | VAF 24/276 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.232); catalogued as rs759096904, COSV56825133; called by muse, mutect2
- KIAA1614 | c.2684del p.G895Efs*106 | Frame Shift Del (DEL) | VAF 70/751 reads (9%) | catalogued as COSV62552001; called by mutect2, pindel
- KIF26A | c.2434C>T p.P812S | Missense Mutation (SNP) | VAF 100/1035 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59465200; called by muse, mutect2
- KIF7 | c.2482G>A p.V828M | Missense Mutation (SNP) | VAF 64/829 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as rs143915145, CM1511082; ClinVar: uncertain significance; called by muse, mutect2
- KL | c.820-1G>T p.X274_splice | Splice Site (SNP) | VAF 16/307 reads (5%) | catalogued as COSV66308908; called by muse, mutect2
- KLF4 | c.779C>A p.P260Q | Missense Mutation (SNP) | VAF 46/716 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV65928994; called by muse, mutect2
- KLHL21 | c.1546G>A p.V516I | Missense Mutation (SNP) | VAF 116/567 reads (20%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.989); catalogued as rs369981047; called by muse, mutect2, varscan2
- KLHL31 | c.1502C>T p.T501I | Missense Mutation (SNP) | VAF 81/726 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.306); catalogued as rs1166104661; called by muse, mutect2, varscan2
- KLHL34 | c.614G>A p.R205Q | Missense Mutation (SNP) | VAF 86/828 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV101069894; called by muse, varscan2
- KLK5 | c.21del p.W8Gfs*8 | Frame Shift Del (DEL) | VAF 39/422 reads (9%) | catalogued as COSV60449953; called by mutect2, pindel, varscan2
- KNTC1 | c.5634G>A p.M1878I | Missense Mutation (SNP) | VAF 41/379 reads (11%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs1181100198; called by muse, mutect2
- KRT1 | c.347del p.G116Vfs*61 | Frame Shift Del (DEL) | VAF 134/726 reads (18%) | catalogued as rs781403016; called by mutect2, pindel, varscan2
- KRT40 | c.157C>T p.R53C | Missense Mutation (SNP) | VAF 90/684 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV66696667; called by muse, mutect2, varscan2
- KSR1 | c.872del p.P291Hfs*36 (on ENST00000644974 / NM_001367810.1; = p.P154Hfs*36 on NM_014238.2) | Frame Shift Del (DEL) | VAF 50/438 reads (11%) | catalogued as rs750491454; called by mutect2, varscan2
- LAMA5 | c.8003G>A p.R2668Q | Missense Mutation (SNP) | VAF 247/686 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs967471014, COSV53361912; called by muse, mutect2, varscan2
- LAMA5 | c.4385A>G p.H1462R | Missense Mutation (SNP) | VAF 40/760 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.309); catalogued as rs1040861513; called by muse, mutect2
- LGI2 | c.1390del p.A464Pfs*2 | Frame Shift Del (DEL) | VAF 55/469 reads (12%) | catalogued as COSV66122342, COSV66124057; called by mutect2, pindel, varscan2
- LHX1 | c.1139C>T p.S380L | Missense Mutation (SNP) | VAF 105/858 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as rs369179293; called by muse, mutect2, varscan2
- LOXHD1 | c.2035G>A p.A679T | Missense Mutation (SNP) | VAF 62/354 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.09); catalogued as rs779377762; ClinVar: uncertain significance; called by muse, varscan2
- LRFN4 | c.1571del p.G524Vfs*100 | Frame Shift Del (DEL) | VAF 101/819 reads (12%) | catalogued as COSV100540885; called by mutect2, varscan2
- LRP1 | c.12083C>T p.T4028M | Missense Mutation (SNP) | VAF 53/444 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs368572931, COSV99675578; called by muse, mutect2, varscan2
- MAB21L2 | c.873G>A p.W291* | Nonsense Mutation (SNP) | VAF 24/649 reads (4%) | catalogued as COSV100462321; called by muse, mutect2
- MACF1 | c.21008G>A p.R7003Q (on ENST00000372915; = p.R5048Q on NM_012090.5) | Missense Mutation (SNP) | VAF 78/432 reads (18%) | catalogued as rs570585623, COSV57127627; called by muse, mutect2, varscan2
- MADD | c.3107G>A p.S1036N | Missense Mutation (SNP) | VAF 84/428 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as rs1260299500; called by muse, varscan2
- MAGEL2 | c.2203C>T p.R735C | Missense Mutation (SNP) | VAF 88/589 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs753238325; called by muse, mutect2, varscan2
- MAGEL2 | c.1376G>A p.R459H | Missense Mutation (SNP) | VAF 122/1184 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.696); catalogued as rs1038598112; called by muse, mutect2
- MAPRE3 | c.53A>G p.H18R | Missense Mutation (SNP) | VAF 108/496 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.221); catalogued as rs1175991309; called by muse, mutect2, varscan2
- MC5R | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 70/651 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.035); catalogued as rs745354606, COSV100228934; called by muse, mutect2, varscan2
- MCM10 | c.2358C>T p.C786= (on ENST00000484800 / NM_182751.3; = p.C785= on NM_018518.5) | Splice Region (SNP) | VAF 30/354 reads (8%) | catalogued as rs536238621; called by muse, mutect2
- MCM3 | c.454G>A p.V152I (on ENST00000229854 / NM_001366374.2; = p.V142I on NM_002388.6 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 43/331 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.202); catalogued as rs1033238760, COSV57719478; called by muse, mutect2, varscan2
- MECOM | c.3106G>A p.A1036T (on ENST00000468789 / NM_001105078.4; = p.A1224T on NM_004991.4) | Missense Mutation (SNP) | VAF 51/500 reads (10%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.984); catalogued as rs747301473; called by muse, mutect2, varscan2
- MEN1 | c.1730C>T p.S577L | Missense Mutation (SNP) | VAF 28/700 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as CD993825, CM077299, COSV53640753; called by muse, mutect2
- MEX3A | c.727G>T p.G243W | Missense Mutation (SNP) | VAF 65/632 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101348923; called by muse, mutect2, varscan2
- MFSD6L | c.358G>A p.A120T | Missense Mutation (SNP) | VAF 66/560 reads (12%) | SIFT tolerated (0.6); PolyPhen benign (0.138); catalogued as rs377558334; called by muse, mutect2, varscan2
- MICALL1 | c.1024G>A p.G342R | Missense Mutation (SNP) | VAF 38/320 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1222598999, COSV53240482; called by muse, varscan2
- MIDEAS | c.939del p.N314Tfs*4 | Frame Shift Del (DEL) | VAF 67/445 reads (15%) | catalogued as rs762448666; called by mutect2, pindel, varscan2
- MISP | c.1513C>T p.R505C | Missense Mutation (SNP) | VAF 88/853 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs762452224, COSV53120588; called by muse, mutect2
- MMP19 | c.334C>T p.R112C | Missense Mutation (SNP) | VAF 48/410 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs145869255; called by muse, mutect2, varscan2
- MPST | c.550C>T p.R184* (on ENST00000341116 / NM_001369904.2; = p.R204* on NM_021126.7 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 76/614 reads (12%) | catalogued as rs769715740, COSV62017746, COSV62018303; called by muse, mutect2, varscan2
- MTHFR | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 92/477 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.421); catalogued as rs777918196, COSV64877411; called by muse, mutect2, varscan2
- MTMR11 | c.1909C>T p.R637C (on ENST00000439741 / NM_001145862.2; = p.R565C on NM_181873.3) | Missense Mutation (SNP) | VAF 58/475 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs371578546; called by muse, mutect2, varscan2
- MXRA8 | c.901del p.R301Gfs*107 | Frame Shift Del (DEL) | VAF 111/687 reads (16%) | catalogued as rs764857791; called by mutect2, pindel, varscan2
- MYADML2 | c.460G>A p.G154S | Missense Mutation (SNP) | VAF 78/729 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1055206854; called by muse, mutect2, varscan2
- MYCBP2 | c.11150C>T p.A3717V (on ENST00000357337; = p.A3755V on NM_015057.5) | Missense Mutation (SNP) | VAF 67/496 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100629045; called by muse, mutect2, varscan2
- MYH10 | c.3400C>T p.R1134W | Missense Mutation (SNP) | VAF 56/494 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52594711; called by muse, varscan2
- MYH11 | c.4637C>T p.T1546M | Missense Mutation (SNP) | VAF 96/670 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs753685135, COSV55556242; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH11 | c.2179C>T p.R727C | Missense Mutation (SNP) | VAF 75/366 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1401359617, COSV55554511; called by muse, varscan2
- MYO1F | c.3037C>T p.Q1013* | Nonsense Mutation (SNP) | VAF 53/419 reads (13%) | catalogued as COSV100597125; called by muse, mutect2, varscan2
- MYO3B | c.841C>T p.R281* | Nonsense Mutation (SNP) | VAF 29/358 reads (8%) | catalogued as rs375096596; called by muse, mutect2
- MYORG | c.1084G>A p.D362N | Missense Mutation (SNP) | VAF 25/602 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV104399916; called by muse, mutect2
- N4BP2 | c.2127del p.Y711Ifs*45 | Frame Shift Del (DEL) | VAF 40/390 reads (10%) | catalogued as COSV54704602; called by mutect2, pindel, varscan2
- NAPRT | c.567C>T p.G189= | Splice Region (SNP) | VAF 103/561 reads (18%) | catalogued as rs1179007077; called by muse, mutect2, varscan2
- NCBP2 | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 85/408 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.849); catalogued as rs1433793609, COSV58318059; called by muse, mutect2, varscan2
- NEURL4 | c.1499C>T p.A500V | Missense Mutation (SNP) | VAF 145/694 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.98); catalogued as rs573288123, COSV59759170; called by muse, mutect2, varscan2
- NKX6-2 | c.694G>T p.A232S | Missense Mutation (SNP) | VAF 120/826 reads (15%) | SIFT tolerated (0.63); PolyPhen benign (0.13); catalogued as rs1386341891, COSV100888351; called by muse, mutect2, varscan2
- NSMAF | c.919C>T p.R307C | Missense Mutation (SNP) | VAF 117/451 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs779054438; called by muse, mutect2, varscan2
- NUCB2 | c.650A>G p.H217R | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV60375143; called by muse, mutect2
- OCIAD1 | c.323C>T p.S108F | Missense Mutation (SNP) | VAF 48/446 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765644170, COSV51901916; called by muse, mutect2, varscan2
- OPRK1 | c.1060C>T p.R354W | Missense Mutation (SNP) | VAF 56/475 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.209); catalogued as rs202165724, COSV55570192; called by muse, mutect2, varscan2
- OR10AC1 | c.794C>T p.A265V | Missense Mutation (SNP) | VAF 121/607 reads (20%) | SIFT tolerated, low confidence (0.11); catalogued as rs1258162499; called by muse, mutect2, varscan2
- OR56B1 | c.16G>T p.A6S | Missense Mutation (SNP) | VAF 121/312 reads (39%) | SIFT tolerated (0.43); PolyPhen benign (0.017); catalogued as COSV57723320; called by muse, mutect2, varscan2
- ORAI2 | c.19G>A p.V7M | Missense Mutation (SNP) | VAF 94/413 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.537); catalogued as rs375636106; called by muse, varscan2
- ORC1 | c.2030G>A p.C677Y | Missense Mutation (SNP) | VAF 26/222 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV65365081; called by muse, varscan2
- PADI6 | c.992C>T p.T331I | Missense Mutation (SNP) | VAF 19/382 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.743); catalogued as rs1300346813, COSV100639918; called by muse, mutect2
- PARP14 | c.2438G>A p.R813Q | Missense Mutation (SNP) | VAF 62/518 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs922423588, COSV101506220; called by muse, mutect2, varscan2
- PCDH7 | c.3097G>A p.A1033T | Missense Mutation (SNP) | VAF 24/553 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV62338833; called by muse, mutect2
- PCDHA9 | c.1061C>T p.T354M | Missense Mutation (SNP) | VAF 32/688 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.336); catalogued as COSV65333855; called by muse, mutect2
- PCDHGA1 | c.1552C>T p.R518* | Nonsense Mutation (SNP) | VAF 162/462 reads (35%) | catalogued as rs781690081, COSV65295069; called by muse, mutect2, varscan2
- PCDHGA4 | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 28/482 reads (6%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.802); catalogued as rs1462167461, COSV99537465; called by muse, mutect2
- PCDHGC3 | c.874C>T p.R292W | Missense Mutation (SNP) | VAF 91/558 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV52768976; called by muse, mutect2, varscan2
- PCSK4 | c.2149G>A p.V717M | Missense Mutation (SNP) | VAF 74/589 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs775533550; called by muse, varscan2
- PDCD1 | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 70/783 reads (9%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs1199002540; called by muse, mutect2
- PDCD1 | c.127G>A p.V43M | Missense Mutation (SNP) | VAF 26/814 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as rs368829632, COSV99044110; called by muse, mutect2
- PDCL3 | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 36/436 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.718); catalogued as rs777385726, COSV51809791; called by muse, mutect2
- PDIA2 | c.1247C>T p.P416L | Missense Mutation (SNP) | VAF 52/433 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs562178952; called by muse, mutect2, varscan2
- PDZD3 | c.1682C>T p.A561V (on ENST00000531114; = p.A481V on NM_024791.4) | Missense Mutation (SNP) | VAF 47/302 reads (16%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs866192091; called by muse, mutect2, varscan2
- PDZD7 | c.2542G>A p.A848T | Missense Mutation (SNP) | VAF 114/657 reads (17%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.911); catalogued as rs1303874165; called by muse, mutect2, varscan2
- PDZD7 | c.1232C>T p.A411V | Missense Mutation (SNP) | VAF 32/934 reads (3%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV64647252; called by muse, mutect2
- PELP1 | c.2392del p.L798Cfs*14 | Frame Shift Del (DEL) | VAF 33/283 reads (12%) | catalogued as rs752653446, COSV99342923; called by mutect2, pindel, varscan2
- PGBD4 | c.1753del p.Y585Ifs*20 | Frame Shift Del (DEL) | VAF 64/378 reads (17%) | catalogued as COSV56626432; called by mutect2, pindel, varscan2
- PHOX2B | c.764C>T p.A255V | Missense Mutation (SNP) | VAF 31/239 reads (13%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV56930550; called by muse, varscan2
- PITPNM2 | c.3967C>T p.R1323C | Missense Mutation (SNP) | VAF 80/883 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs1339998437, COSV54902414; called by muse, mutect2
- PKD2 | c.794C>T p.T265M | Missense Mutation (SNP) | VAF 58/442 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs569250922; called by muse, mutect2, varscan2
- PKHD1L1 | c.6851G>T p.R2284L | Missense Mutation (SNP) | VAF 53/338 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101005302, COSV65747020; called by muse, varscan2
- PLA2G4F | c.2087A>G p.Q696R | Missense Mutation (SNP) | VAF 54/524 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs1477822774; called by muse, mutect2, varscan2
- PLEC | c.196G>A p.A66T | Missense Mutation (SNP) | VAF 102/1004 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.185); catalogued as COSV100519660; called by muse, mutect2
- PLXNB2 | c.5201C>T p.S1734F | Missense Mutation (SNP) | VAF 169/439 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63782393; called by muse, mutect2, varscan2
- PNMA6E | c.118C>T p.R40W | Missense Mutation (SNP) | VAF 44/602 reads (7%) | SIFT tolerated (0.09); catalogued as rs1180045578; called by muse, mutect2
- PODN | c.1252G>A p.A418T (on ENST00000395871; = p.A370T on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 54/759 reads (7%) | SIFT tolerated (0.67); PolyPhen benign (0.194); catalogued as rs143961951; called by muse, mutect2
- POU2F2 | c.1285del p.L429Sfs*34 (on ENST00000526816 / NM_001207025.3; = p.L413Sfs*34 on NM_002698.5) | Frame Shift Del (DEL) | VAF 36/282 reads (13%) | catalogued as rs746693584, COSV60766181; called by mutect2, varscan2
- POU3F4 | c.715C>T p.Q239* | Nonsense Mutation (SNP) | VAF 46/500 reads (9%) | catalogued as COSV64540491; called by muse, mutect2
- PPFIA2 | c.3171del p.D1058Ifs*6 | Frame Shift Del (DEL) | VAF 40/345 reads (12%) | catalogued as rs1196615164; called by mutect2, pindel, varscan2
- PPIF | c.403G>A p.V135M | Missense Mutation (SNP) | VAF 39/312 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.444); catalogued as rs144470581; called by muse, mutect2, varscan2
- PPM1L | c.794G>A p.R265Q | Missense Mutation (SNP) | VAF 44/510 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1214162439, COSV55565633; called by muse, mutect2
- PPP1R10 | c.2808del p.L939Cfs*109 | Frame Shift Del (DEL) | VAF 133/626 reads (21%) | catalogued as COSV64738548; called by mutect2, pindel, varscan2
- PPP1R37 | c.1229C>T p.S410L | Missense Mutation (SNP) | VAF 77/567 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs1256693172; called by muse, mutect2, varscan2
- PPP1R3F | c.1193C>T p.P398L | Missense Mutation (SNP) | VAF 122/699 reads (17%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.06); catalogued as rs1557121325, COSV99278999; called by muse, mutect2, varscan2
- PRKAR1B | c.106G>A p.V36I | Missense Mutation (SNP) | VAF 70/518 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.159); catalogued as rs764518494, COSV64320093; called by muse, mutect2, varscan2
- PRPF8 | c.1240C>T p.R414C | Missense Mutation (SNP) | VAF 36/971 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs368865707; ClinVar: uncertain significance; called by muse, mutect2
- PTEN | c.800dup p.D268Gfs*30 | Frame Shift Ins (INS) | VAF 32/279 reads (11%) | catalogued as COSV64302388; called by mutect2, pindel, varscan2
- PTPRD | c.5285G>A p.R1762Q | Missense Mutation (SNP) | VAF 27/258 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.606); catalogued as rs374969402; called by muse, mutect2, varscan2
- PTPRF | c.5362C>T p.R1788W | Missense Mutation (SNP) | VAF 38/358 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746786262; called by muse, mutect2, varscan2
- PXDN | c.2990G>A p.R997H | Missense Mutation (SNP) | VAF 261/670 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV53237101; called by muse, mutect2, varscan2
- PXDN | c.2810G>A p.R937Q | Missense Mutation (SNP) | VAF 39/845 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.733); catalogued as rs1440817288; called by muse, mutect2
- PYCR1 | c.238G>A p.D80N | Missense Mutation (SNP) | VAF 28/645 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.357); catalogued as rs1240631685; called by muse, mutect2
- QRICH2 | c.2377C>T p.R793C | Missense Mutation (SNP) | VAF 62/472 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); catalogued as rs770473019; called by muse, mutect2, varscan2
- R3HDML | c.389C>T p.S130F | Missense Mutation (SNP) | VAF 40/353 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV53836157, COSV99407203; called by muse, mutect2, varscan2
- RALGAPA2 | c.4931G>A p.R1644H | Missense Mutation (SNP) | VAF 46/248 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs763921980, COSV99173532; called by muse, mutect2, varscan2
- RASSF7 | c.575G>A p.R192H | Missense Mutation (SNP) | VAF 106/944 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.087); catalogued as rs541975669; called by muse, mutect2, varscan2
- RBM10 | c.292C>T p.R98* | Nonsense Mutation (SNP) | VAF 180/797 reads (23%) | catalogued as COSV61307911, COSV61308269, COSV61311988; called by muse, varscan2
- RBM10 | c.2704C>T p.R902W | Missense Mutation (SNP) | VAF 27/642 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs782208940; called by muse, mutect2
- RBM15 | c.2671C>A p.L891I | Missense Mutation (SNP) | VAF 46/576 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100873542; called by muse, mutect2
- RERE | c.4530del p.M1511Cfs*48 | Frame Shift Del (DEL) | VAF 84/778 reads (11%) | catalogued as COSV61941733; called by mutect2, pindel
- RFX2 | c.1991C>T p.T664M | Missense Mutation (SNP) | VAF 79/480 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs781066965; called by muse, mutect2, varscan2
- RNF20 | c.730C>T p.R244C | Missense Mutation (SNP) | VAF 24/252 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs564171193, COSV66355840; called by muse, varscan2
- RNF213 | c.10088G>A p.R3363Q | Missense Mutation (SNP) | VAF 51/365 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.394); catalogued as rs745952693, COSV60389636; called by muse, mutect2, varscan2
- ROR1 | c.2443C>T p.R815* | Nonsense Mutation (SNP) | VAF 27/752 reads (4%) | catalogued as COSV100935298; called by muse, mutect2
- RPAP1 | c.3884C>T p.A1295V | Missense Mutation (SNP) | VAF 64/602 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs369609807; called by muse, mutect2, varscan2
- RPIA | c.791G>A p.R264Q | Missense Mutation (SNP) | VAF 126/326 reads (39%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as rs748446592; called by muse, mutect2, varscan2
- RRP8 | c.539C>A p.P180H | Missense Mutation (SNP) | VAF 48/554 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.671); catalogued as COSV54450400; called by muse, mutect2
- RTTN | c.4772G>A p.R1591Q | Missense Mutation (SNP) | VAF 87/451 reads (19%) | SIFT tolerated (0.62); PolyPhen benign (0.005); catalogued as rs543724689, COSV55344567; called by muse, mutect2, varscan2
- RUVBL2 | c.62G>A p.R21Q | Missense Mutation (SNP) | VAF 49/466 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1380097132, COSV104379699; called by muse, mutect2, varscan2
- RXFP3 | c.1276C>T p.H426Y | Missense Mutation (SNP) | VAF 106/918 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs759363046; called by muse, mutect2, varscan2
- RYR3 | c.9230C>T p.S3077L (on ENST00000389232; = p.S3078L on NM_001036.6) | Missense Mutation (SNP) | VAF 40/455 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs1465857409, COSV66783537; called by muse, mutect2
- SAMD4A | c.1621del p.R541Dfs*22 | Frame Shift Del (DEL) | VAF 38/330 reads (12%) | catalogued as rs1566630333; called by mutect2, pindel, varscan2
- SBK2 | c.467C>T p.P156L | Missense Mutation (SNP) | VAF 117/586 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1264260555; called by muse, mutect2, varscan2
- SEC16A | c.2344C>T p.R782* | Nonsense Mutation (SNP) | VAF 58/508 reads (11%) | catalogued as rs758756567; called by muse, mutect2, varscan2
- SEMA4F | c.2174G>A p.R725Q | Missense Mutation (SNP) | VAF 103/556 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.968); catalogued as rs373277680; called by muse, varscan2
- SEMA6A | c.2993C>T p.S998L | Missense Mutation (SNP) | VAF 64/572 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.247); catalogued as rs781118630, COSV56714923; called by muse, mutect2, varscan2
- SETD9 | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 28/376 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV53650139; called by muse, mutect2
- SH3BP2 | c.823del p.R275Efs*3 | Frame Shift Del (DEL) | VAF 90/797 reads (11%) | catalogued as rs776466609, COSV62555238; called by mutect2, pindel, varscan2
- SH3PXD2A | c.328dup p.H110Pfs*6 | Frame Shift Ins (INS) | VAF 46/404 reads (11%) | catalogued as rs777796332; called by mutect2, varscan2
- SH3PXD2B | c.2572G>A p.V858M | Missense Mutation (SNP) | VAF 236/654 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.176); catalogued as rs758060713; called by muse, mutect2, varscan2
- SHMT2 | c.74G>A p.R25Q | Missense Mutation (SNP) | VAF 52/593 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs375322221, COSV100196899; called by muse, mutect2
- SHROOM3 | c.2801G>A p.R934H | Missense Mutation (SNP) | VAF 28/882 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1292544124, COSV56027551; called by muse, mutect2
- SIN3A | c.3788G>A p.R1263H | Missense Mutation (SNP) | VAF 93/470 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.068); catalogued as rs908805435; called by muse, mutect2, varscan2
- SLC12A1 | c.2929G>A p.G977S | Missense Mutation (SNP) | VAF 26/360 reads (7%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.631); catalogued as rs372350814; ClinVar: likely benign; called by muse, mutect2
- SLC25A42 | c.580G>A p.V194M | Missense Mutation (SNP) | VAF 72/556 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.067); catalogued as rs773840865, COSV100588126; called by muse, mutect2, varscan2
- SLC26A6 | c.1738C>T p.L580F | Missense Mutation (SNP) | VAF 52/528 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.601); catalogued as rs774406934; called by muse, mutect2
- SLC30A3 | c.844G>A p.A282T | Missense Mutation (SNP) | VAF 49/434 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.65); catalogued as rs1400202057, CM146185, COSV51987367; called by muse, mutect2, varscan2
- SLC35B1 | c.521C>T p.P174L (on ENST00000649906; = p.P137L on NM_005827.4) | Missense Mutation (SNP) | VAF 88/466 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs556185582, COSV99539602; called by muse, mutect2, varscan2
- SLC35E1 | c.448G>T p.V150F | Missense Mutation (SNP) | VAF 40/428 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54661479; called by muse, mutect2
- SLC4A2 | c.937C>T p.R313* | Nonsense Mutation (SNP) | VAF 106/501 reads (21%) | catalogued as COSV59655896; called by muse, mutect2, varscan2
- SLC8B1 | c.423C>T p.G141= | Splice Region (SNP) | VAF 17/372 reads (5%) | catalogued as rs1566238954, COSV99176671; called by muse, mutect2
- SLITRK4 | c.1136C>T p.A379V | Missense Mutation (SNP) | VAF 22/738 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs782089060, COSV62023856; called by muse, mutect2
- SMARCA4 | c.4328G>T p.R1443L | Missense Mutation (SNP) | VAF 46/808 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV60793371; called by muse, mutect2
- SMARCC2 | c.2743C>T p.R915W | Missense Mutation (SNP) | VAF 38/341 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV57213988; called by muse, mutect2, varscan2
- SMC1B | c.74G>A p.R25Q | Missense Mutation (SNP) | VAF 72/649 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs768603770, COSV61581080; called by muse, mutect2, varscan2
- SMCO3 | c.43C>T p.R15W | Missense Mutation (SNP) | VAF 63/412 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs781434492, COSV53763605, COSV53763611; called by muse, mutect2, varscan2
- SMYD4 | c.2119C>T p.R707W | Missense Mutation (SNP) | VAF 65/589 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as rs746682269, COSV59711904; called by muse, mutect2, varscan2
- SOGA3 | c.722del p.G241Afs*133 | Frame Shift Del (DEL) | VAF 70/728 reads (10%) | catalogued as rs778091058, COSV100846885; called by mutect2, pindel
- SOX15 | c.128C>T p.T43M | Missense Mutation (SNP) | VAF 157/858 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as rs557247017; called by muse, mutect2, varscan2
- SPATA1 | c.166C>T p.R56* | Nonsense Mutation (SNP) | VAF 39/337 reads (12%) | catalogued as rs377559628, COSV99759663; called by muse, mutect2, varscan2
- SPATA2 | c.665C>T p.T222M | Missense Mutation (SNP) | VAF 85/727 reads (12%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.88); catalogued as rs756953070; called by muse, mutect2, varscan2
- SPEM2 | c.779G>A p.R260H | Missense Mutation (SNP) | VAF 84/709 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.36); catalogued as rs761186084, COSV61603474; called by muse, mutect2, varscan2
- SPIC | c.314del p.G105Efs*29 | Frame Shift Del (DEL) | VAF 74/374 reads (20%) | catalogued as rs1565832463, COSV54691823; called by mutect2, pindel, varscan2
- SPINK5 | c.715dup p.C239Lfs*6 | Frame Shift Ins (INS) | VAF 40/390 reads (10%) | catalogued as rs773514258; called by mutect2, pindel, varscan2
- SPIRE1 | c.2219C>T p.S740L (on ENST00000409402 / NM_001128626.2; = p.S726L on NM_020148.3) | Missense Mutation (SNP) | VAF 129/398 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.727); catalogued as COSV104400592; called by muse, varscan2
- SPTB | c.983G>A p.R328H | Missense Mutation (SNP) | VAF 62/680 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs779720812, COSV67635814; called by muse, mutect2
- SRPRA | c.1273G>A p.G425S | Missense Mutation (SNP) | VAF 51/428 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs764757201; called by muse, mutect2, varscan2
- STARD9 | c.12913C>T p.R4305C | Missense Mutation (SNP) | VAF 38/379 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs561723739, COSV51906484; called by muse, varscan2
- STX16 | c.712C>T p.R238* (on ENST00000371141 / NM_001001433.3; = p.R217* on NM_003763.6) | Nonsense Mutation (SNP) | VAF 106/521 reads (20%) | catalogued as rs759584494, COSV56604294; called by muse, varscan2
- TACC1 | c.1727C>T p.S576F | Missense Mutation (SNP) | VAF 26/280 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.195); catalogued as COSV52523334; called by muse, mutect2
- TAF1 | c.4633C>T p.R1545W (on ENST00000373790 / NM_138923.4; = p.R1566W on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 141/411 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.845); catalogued as COSV52120874; called by muse, mutect2, varscan2
- TAF3 | c.2566G>A p.V856M | Missense Mutation (SNP) | VAF 26/484 reads (5%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV60202976; called by muse, mutect2
- TAS1R1 | c.1664G>A p.R555H | Missense Mutation (SNP) | VAF 62/516 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs142426315; called by muse, varscan2
- TAS2R42 | c.608del p.L203Yfs*6 | Frame Shift Del (DEL) | VAF 49/421 reads (12%) | catalogued as rs751188508; called by mutect2, pindel, varscan2
- TASOR2 | c.1154C>T p.P385L | Missense Mutation (SNP) | VAF 48/397 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.36); catalogued as rs914632684; called by muse, mutect2, varscan2
- TBC1D8 | c.862C>T p.R288W | Missense Mutation (SNP) | VAF 40/546 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs1003818142, COSV65214741; called by muse, mutect2
- TBCD | c.3307G>A p.G1103S | Missense Mutation (SNP) | VAF 117/598 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as rs772606107; called by muse, mutect2, varscan2
- TBX6 | c.46C>T p.R16C | Missense Mutation (SNP) | VAF 46/715 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.006); catalogued as rs1199593276; called by muse, mutect2
- TENM3 | c.7873C>T p.R2625W | Missense Mutation (SNP) | VAF 31/317 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV69308587; called by muse, mutect2, varscan2
- TESK2 | c.1453C>T p.R485C | Missense Mutation (SNP) | VAF 86/477 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.642); catalogued as rs754978881, COSV59149445; called by muse, mutect2, varscan2
- TMEM176B | c.496C>T p.R166C | Missense Mutation (SNP) | VAF 42/448 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs750751165, COSV58440244; called by muse, mutect2
- TMEM26 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 27/319 reads (8%) | SIFT tolerated (0.57); PolyPhen benign (0.031); catalogued as rs573061733; called by muse, mutect2
- TMEM268 | c.102del p.Q35Kfs*57 | Frame Shift Del (DEL) | VAF 66/516 reads (13%) | catalogued as rs766318080; called by mutect2, pindel, varscan2
- TMEM63A | c.2285C>T p.S762L | Missense Mutation (SNP) | VAF 144/456 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.304); catalogued as rs780727416; called by muse, varscan2
- TMEM65 | c.604C>T p.R202C | Missense Mutation (SNP) | VAF 24/297 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.165); catalogued as rs779556138, COSV52629536; called by muse, mutect2
- TNS3 | c.2683G>A p.A895T | Missense Mutation (SNP) | VAF 67/460 reads (15%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs376502421; called by muse, mutect2, varscan2
- TNXB | c.12163C>T p.R4055W (on ENST00000647633; = p.R3808W on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 102/686 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs149197999; called by muse, mutect2, varscan2
- TOGARAM1 | c.502del p.E168Rfs*11 | Frame Shift Del (DEL) | VAF 45/459 reads (10%) | catalogued as COSV61887381; called by mutect2, pindel, varscan2
- TP73 | c.1172A>G p.Q391R | Missense Mutation (SNP) | VAF 93/418 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.246); catalogued as rs530995550, COSV60698163; called by muse, mutect2, varscan2
- TRHDE | c.374C>T p.P125L | Missense Mutation (SNP) | VAF 163/739 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV53862529; called by muse, mutect2, varscan2
- TRIM59 | c.614C>T p.T205M | Missense Mutation (SNP) | VAF 34/326 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.197); catalogued as rs779124243, COSV59086784; called by muse, varscan2
- TRPV2 | c.1609C>A p.R537S | Missense Mutation (SNP) | VAF 50/490 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs765501713; called by muse, mutect2
- TSC22D2 | c.88A>G p.T30A | Missense Mutation (SNP) | VAF 28/600 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as rs1197824161; called by muse, mutect2
- TTBK1 | c.1576G>A p.A526T | Missense Mutation (SNP) | VAF 151/692 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52489714; called by muse, mutect2, varscan2
- TTN | c.11111C>T p.T3704I (on ENST00000591111; = p.T3658I on NM_003319.4) | Missense Mutation (SNP) | VAF 59/578 reads (10%) | catalogued as COSV60345803; called by muse, mutect2, varscan2
- UBR5 | c.925C>T p.R309C | Missense Mutation (SNP) | VAF 36/484 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs1016575363; called by muse, mutect2
- UBTD2 | c.253G>C p.D85H | Missense Mutation (SNP) | VAF 53/386 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV67143193; called by muse, mutect2, varscan2
- UCN2 | c.164C>T p.P55L | Missense Mutation (SNP) | VAF 69/756 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs777675487, COSV56476379; called by muse, mutect2
- ULK1 | c.1976G>A p.R659Q | Missense Mutation (SNP) | VAF 173/794 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.685); catalogued as rs377611474; called by muse, mutect2, varscan2
- UNC45B | c.1551G>A p.W517* | Nonsense Mutation (SNP) | VAF 96/377 reads (25%) | catalogued as rs1237412903, COSV52096028; called by muse, mutect2, varscan2
- UNC93A | c.791C>T p.P264L | Missense Mutation (SNP) | VAF 77/378 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs759479832; called by muse, mutect2, varscan2
- USP49 | c.971C>T p.A324V | Missense Mutation (SNP) | VAF 65/604 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.04); catalogued as rs760389495; called by muse, mutect2, varscan2
- VDAC3 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 100/535 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.268); catalogued as rs775234791, COSV50081244; called by muse, varscan2
- VILL | c.1438del p.H480Tfs*11 | Frame Shift Del (DEL) | VAF 76/665 reads (11%) | catalogued as rs753585188; called by mutect2, pindel, varscan2
- VWF | c.1442G>A p.R481H | Missense Mutation (SNP) | VAF 60/572 reads (10%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.996); catalogued as rs772554807, COSV99780239; called by muse, mutect2
- WDTC1 | c.868del p.E290Nfs*8 | Frame Shift Del (DEL) | VAF 116/264 reads (44%) | catalogued as rs747972901, COSV60089251; called by mutect2, varscan2
- YIPF2 | c.409G>A p.V137I | Missense Mutation (SNP) | VAF 55/446 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1455208697; called by muse, mutect2, varscan2
- ZBTB5 | c.359C>T p.T120M | Missense Mutation (SNP) | VAF 103/473 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759066956, COSV57040195; called by muse, mutect2, varscan2
- ZBTB8A | c.1297G>A p.E433K | Missense Mutation (SNP) | VAF 35/295 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.105); catalogued as rs1162929155; called by muse, mutect2, varscan2
- ZC3H12A | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 113/526 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1035304408; called by muse, mutect2, varscan2
- ZC3H18 | c.2153C>T p.S718L | Missense Mutation (SNP) | VAF 113/550 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1337817117; called by muse, mutect2, varscan2
- ZFAT | c.1084_1086del p.K362del | In Frame Del (DEL) | VAF 52/500 reads (10%) | catalogued as rs767616893; called by pindel, varscan2
- ZFYVE26 | c.1345C>T p.H449Y | Missense Mutation (SNP) | VAF 50/596 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.756); catalogued as COSV61330240; called by muse, mutect2
- ZMYND11 | c.1000C>T p.R334W | Missense Mutation (SNP) | VAF 37/452 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as rs369984743; called by muse, mutect2
- ZNF114 | c.943dup p.Y315Lfs*19 | Frame Shift Ins (INS) | VAF 32/277 reads (12%) | catalogued as rs751350196; called by mutect2, varscan2
- ZNF182 | c.1319C>T p.T440M | Missense Mutation (SNP) | VAF 50/764 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.703); catalogued as rs374396469; called by muse, mutect2
- ZNF283 | c.353C>T p.T118M | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.36); catalogued as rs1329482809, COSV100190446; called by muse, mutect2, varscan2
- ZNF524 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 21/790 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1230950890; called by muse, mutect2
- ZNF536 | c.1556A>G p.N519S | Missense Mutation (SNP) | VAF 123/610 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.037); catalogued as rs1028160142, COSV100835996; called by muse, mutect2, varscan2
- ZNF568 | c.830C>T p.P277L | Missense Mutation (SNP) | VAF 58/338 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as rs371204967; called by muse, mutect2, varscan2
- ZNF577 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 89/423 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs752209036, COSV56814648; called by muse, mutect2, varscan2
- ZNF648 | c.821G>C p.G274A | Missense Mutation (SNP) | VAF 72/830 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs754881990, COSV60569527; called by muse, mutect2
- ZNF709 | c.1850C>T p.A617V | Missense Mutation (SNP) | VAF 100/448 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV67195780; called by muse, varscan2
- ZNF724 | c.1199G>A p.G400D | Missense Mutation (SNP) | VAF 32/380 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.484); catalogued as rs777760654; called by muse, mutect2
- ZNF726 | c.1372T>C p.C458R | Missense Mutation (SNP) | VAF 44/345 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1167355789; called by muse, mutect2, varscan2
- ZNF764 | c.919C>T p.R307C | Missense Mutation (SNP) | VAF 78/695 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.721); catalogued as rs1162580996; called by muse, mutect2, varscan2
- ZNF821 | c.500G>A p.R167H (on ENST00000425432 / NM_001376297.1; = p.R125H on NM_017530.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 63/589 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1268556840; called by muse, mutect2
- AASS | c.1945A>G p.K649E | Missense Mutation (SNP) | VAF 23/554 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ABCC11 | c.1175T>C p.I392T | Missense Mutation (SNP) | VAF 64/666 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.015); called by muse, mutect2
- ABCC2 | c.4386G>T p.E1462D | Missense Mutation (SNP) | VAF 26/598 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ABCD1 | c.1196T>C p.I399T | Missense Mutation (SNP) | VAF 87/602 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ABCD2 | c.635A>G p.E212G | Missense Mutation (SNP) | VAF 59/521 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- ABHD6 | c.962T>A p.I321N | Missense Mutation (SNP) | VAF 95/453 reads (21%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- AC092143.1 | c.1115G>A p.S372N | Missense Mutation (SNP) | VAF 32/514 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2
- AC099489.1 | c.9793T>C p.C3265R | Missense Mutation (SNP) | VAF 76/351 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- ACADVL | c.800T>C p.V267A | Missense Mutation (SNP) | VAF 176/433 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- ACOT11 | c.559T>C p.Y187H | Missense Mutation (SNP) | VAF 55/743 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ACOT11 | c.1284G>A p.M428I | Missense Mutation (SNP) | VAF 48/591 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2
- ACSM5 | c.592C>T p.P198S | Missense Mutation (SNP) | VAF 40/355 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.038); called by muse, varscan2
- ACTN3 | c.2673C>A p.F891L | Missense Mutation (SNP) | VAF 59/563 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ADAM12 | c.37G>A p.A13T | Missense Mutation (SNP) | VAF 67/442 reads (15%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- ADAMTSL4 | c.1894G>A p.A632T | Missense Mutation (SNP) | VAF 40/612 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2
- ADAP1 | c.424G>C p.D142H | Missense Mutation (SNP) | VAF 153/473 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- AGRN | c.1896_1897dup p.G633Vfs*100 | Frame Shift Ins (INS) | VAF 124/569 reads (22%) | called by mutect2, varscan2
- AHCTF1 | c.6279del p.K2093Nfs*15 (on ENST00000366508; = p.K2067Nfs*15 on NM_015446.5) | Frame Shift Del (DEL) | VAF 68/537 reads (13%) | called by mutect2, pindel, varscan2
- AJM1 | c.2572G>A p.A858T | Missense Mutation (SNP) | VAF 36/423 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.007); called by muse, mutect2
- ALMS1 | c.9821C>T p.T3274I | Missense Mutation (SNP) | VAF 54/312 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.481); called by muse, varscan2
- ALOX12 | c.49G>A p.G17R | Missense Mutation (SNP) | VAF 69/607 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AMER1 | c.296T>C p.L99P | Missense Mutation (SNP) | VAF 40/973 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.104); called by muse, mutect2
- ANGPTL6 | c.1190G>A p.S397N | Missense Mutation (SNP) | VAF 42/383 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); called by muse, mutect2, varscan2
- ANKRD17 | c.7093G>A p.A2365T | Missense Mutation (SNP) | VAF 67/537 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ANKRD44 | c.1349A>G p.H450R | Missense Mutation (SNP) | VAF 98/526 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- APBB1IP | c.1553del p.P518Rfs*138 | Frame Shift Del (DEL) | VAF 81/631 reads (13%) | called by mutect2, pindel, varscan2
- ARFGAP1 | c.883dup p.S295Ffs*42 | Frame Shift Ins (INS) | VAF 88/506 reads (17%) | called by mutect2, varscan2
- ARHGEF1 | c.916G>T p.G306W | Missense Mutation (SNP) | VAF 72/749 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- ARHGEF26 | c.563G>A p.G188D | Missense Mutation (SNP) | VAF 22/614 reads (4%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); called by muse, mutect2
- ARID1A | c.6420del p.F2141Sfs*59 | Frame Shift Del (DEL) | VAF 127/719 reads (18%) | called by mutect2, pindel, varscan2
- ARID4A | c.2605del p.I869* | Frame Shift Del (DEL) | VAF 52/288 reads (18%) | called by mutect2, pindel, varscan2
- ARID5B | c.1291del p.E431Kfs*48 | Frame Shift Del (DEL) | VAF 138/404 reads (34%) | called by mutect2, varscan2
- ASCC1 | c.626C>T p.T209I (on ENST00000342444 / NM_001369085.1; = p.T181I on NM_001198798.2 and 8 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 52/507 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATL3 | c.1205A>G p.K402R | Missense Mutation (SNP) | VAF 26/564 reads (5%) | SIFT tolerated (0.72); PolyPhen benign (0.127); called by muse, mutect2
- ATMIN | c.2350G>A p.E784K | Missense Mutation (SNP) | VAF 76/534 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- AVL9 | c.1202C>T p.A401V | Missense Mutation (SNP) | VAF 58/302 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- AZU1 | c.260G>A p.R87K | Missense Mutation (SNP) | VAF 68/853 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.403); called by muse, mutect2
- B2M | c.43_44del p.L15Ffs*41 | Frame Shift Del (DEL) | VAF 88/642 reads (14%) | called by pindel, varscan2
- B3GNT8 | c.512G>A p.W171* | Nonsense Mutation (SNP) | VAF 81/635 reads (13%) | called by muse, mutect2, varscan2
- BAIAP2L2 | c.454C>T p.R152W | Missense Mutation (SNP) | VAF 29/337 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); called by muse, mutect2
- BANP | c.173T>C p.L58S (on ENST00000286122; = p.L66S on NM_017869.4) | Missense Mutation (SNP) | VAF 83/304 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.993); called by muse, varscan2
- BCL9L | c.2445G>T p.E815D | Missense Mutation (SNP) | VAF 58/644 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.437); called by muse, mutect2
- BOD1L1 | c.7640C>T p.A2547V | Missense Mutation (SNP) | VAF 97/533 reads (18%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- BRSK2 | c.773G>A p.R258H | Missense Mutation (SNP) | VAF 47/401 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- BRWD3 | c.4904A>G p.Y1635C | Missense Mutation (SNP) | VAF 69/605 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- BSN | c.10169del p.P3390Hfs*97 | Frame Shift Del (DEL) | VAF 66/738 reads (9%) | called by mutect2, pindel
- BTK | c.472A>G p.T158A | Missense Mutation (SNP) | VAF 106/613 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- BUB1B | c.3090C>G p.H1030Q | Missense Mutation (SNP) | VAF 48/574 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.009); called by muse, mutect2
- C16orf72 | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 52/510 reads (10%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- C2CD4D | c.283C>T p.P95S | Missense Mutation (SNP) | VAF 117/549 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- CACNA1D | c.1865G>A p.R622H (on ENST00000350061 / NM_001128840.3; = p.R642H on NM_000720.4) | Missense Mutation (SNP) | VAF 14/332 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CACNB2 | c.1935del p.K645Nfs*29 (on ENST00000324631 / NM_201596.3; = p.K590Nfs*29 on NM_000724.4) | Frame Shift Del (DEL) | VAF 35/330 reads (11%) | called by mutect2, pindel, varscan2
- CADM2 | c.427C>T p.Q143* (on ENST00000407528 / NM_001167674.2; = p.Q145* on NM_153184.4) | Nonsense Mutation (SNP) | VAF 38/534 reads (7%) | called by muse, mutect2
- CADPS | c.251C>T p.A84V | Missense Mutation (SNP) | VAF 15/248 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2
- CAPN11 | c.785T>C p.L262P | Missense Mutation (SNP) | VAF 42/590 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2
- CARMIL2 | c.3793C>A p.R1265S | Missense Mutation (SNP) | VAF 58/592 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- CAST | c.599C>T p.T200I (on ENST00000341926; = p.T283I on NM_001750.7 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/241 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, varscan2
- CBFA2T3 | c.1579A>G p.M527V | Missense Mutation (SNP) | VAF 48/1042 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); called by muse, mutect2
- CCDC168 | c.15521G>A p.S5174N | Missense Mutation (SNP) | VAF 20/630 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.056); called by muse, mutect2
- CCDC168 | c.12133del p.M4045Wfs*7 | Frame Shift Del (DEL) | VAF 71/349 reads (20%) | called by mutect2, pindel, varscan2
- CCDC170 | c.1126C>T p.L376F | Missense Mutation (SNP) | VAF 28/447 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.178); called by muse, mutect2
- CD151 | c.620G>A p.G207D | Missense Mutation (SNP) | VAF 46/394 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CDC42EP3 | c.629dup p.C211Mfs*9 | Frame Shift Ins (INS) | VAF 127/633 reads (20%) | called by mutect2, pindel, varscan2
- CDH13 | c.806C>T p.A269V | Missense Mutation (SNP) | VAF 38/392 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CDH7 | c.472T>C p.Y158H | Missense Mutation (SNP) | VAF 50/375 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- CENPVL3 | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 124/709 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- CEP162 | c.405del p.F135Lfs*8 | Frame Shift Del (DEL) | VAF 60/352 reads (17%) | called by mutect2, pindel, varscan2
- CHD1 | c.1613C>T p.P538L | Missense Mutation (SNP) | VAF 38/430 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- CHD3 | c.1617_1618del p.R540Sfs*46 | Frame Shift Del (DEL) | VAF 59/723 reads (8%) | called by pindel, varscan2*
- CHD8 | c.7427T>C p.V2476A (on ENST00000646647 / NM_001170629.2; = p.V2197A on NM_020920.4) | Missense Mutation (SNP) | VAF 95/535 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen possibly damaging (0.481); called by muse, mutect2, varscan2
- CHD8 | c.3119del p.N1040Tfs*12 (on ENST00000646647 / NM_001170629.2; = p.N761Tfs*12 on NM_020920.4) | Frame Shift Del (DEL) | VAF 51/460 reads (11%) | called by mutect2, pindel, varscan2
- CHST7 | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 42/912 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- CLCNKB | c.175C>T p.L59F | Missense Mutation (SNP) | VAF 22/491 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.275); called by muse, mutect2
- CLDN19 | c.541T>G p.F181V | Missense Mutation (SNP) | VAF 60/622 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.309); called by muse, mutect2
- CMTM8 | c.46G>A p.A16T | Missense Mutation (SNP) | VAF 42/786 reads (5%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2
- CNGB1 | c.1609G>A p.A537T | Missense Mutation (SNP) | VAF 36/320 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.177); called by muse, mutect2
- CNR1 | c.307A>G p.M103V | Missense Mutation (SNP) | VAF 61/351 reads (17%) | SIFT tolerated (0.59); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CNTNAP3 | c.2414A>G p.H805R | Missense Mutation (SNP) | VAF 13/334 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.358); called by muse, mutect2
- COL12A1 | c.3626G>A p.S1209N | Missense Mutation (SNP) | VAF 131/391 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.518); called by muse, varscan2
- COL21A1 | c.1231G>A p.D411N | Missense Mutation (SNP) | VAF 42/538 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2
- COL4A3 | c.860del p.K287Rfs*36 | Frame Shift Del (DEL) | VAF 53/347 reads (15%) | called by mutect2, pindel, varscan2
- COLEC10 | c.790C>T p.L264F | Missense Mutation (SNP) | VAF 28/401 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.378); called by muse, mutect2
- COMP | c.1094A>G p.D365G | Missense Mutation (SNP) | VAF 80/576 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- COMP | c.878T>C p.V293A | Missense Mutation (SNP) | VAF 29/583 reads (5%) | SIFT tolerated (0.58); PolyPhen benign (0.06); called by muse, mutect2
- CPA4 | c.679G>T p.G227* | Nonsense Mutation (SNP) | VAF 18/368 reads (5%) | called by muse, mutect2
- CPAMD8 | c.1558del p.S520Lfs*2 (on ENST00000651564; = p.S473Lfs*2 on NM_015692.5) | Frame Shift Del (DEL) | VAF 35/372 reads (9%) | called by mutect2, pindel, varscan2
- CPEB2 | c.2912G>A p.R971H | Missense Mutation (SNP) | VAF 24/616 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- CROCC2 | c.2174C>T p.T725I | Missense Mutation (SNP) | VAF 19/378 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.67); called by muse, mutect2
- CSF3 | c.231del p.E78Rfs*17 | Frame Shift Del (DEL) | VAF 58/680 reads (9%) | called by mutect2, pindel
- CSNK2A2 | c.1048C>T p.R350* | Nonsense Mutation (SNP) | VAF 73/383 reads (19%) | called by muse, mutect2, varscan2
- CSRNP3 | c.1057del p.C353Afs*87 | Frame Shift Del (DEL) | VAF 46/482 reads (10%) | called by mutect2, pindel
- CTNS | c.37C>T p.P13S | Missense Mutation (SNP) | VAF 64/312 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CUL9 | c.917T>C p.V306A | Missense Mutation (SNP) | VAF 166/665 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- CYP4F8 | c.1547T>C p.V516A | Missense Mutation (SNP) | VAF 51/487 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- DACH2 | c.1239G>A p.M413I | Missense Mutation (SNP) | VAF 12/310 reads (4%) | SIFT tolerated (0.94); PolyPhen benign (0.001); called by muse, mutect2
- DCDC1 | c.575T>C p.V192A | Missense Mutation (SNP) | VAF 16/327 reads (5%) | SIFT tolerated (0.8); PolyPhen benign (0.015); called by muse, mutect2
- DCLK1 | c.450G>T p.W150C | Missense Mutation (SNP) | VAF 22/526 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- DHX57 | c.2830G>A p.G944R | Missense Mutation (SNP) | VAF 17/408 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.159); called by muse, mutect2
- DHX57 | c.2414C>T p.A805V | Missense Mutation (SNP) | VAF 14/362 reads (4%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2
- DIO2 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 26/507 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DLG2 | c.127C>T p.H43Y | Missense Mutation (SNP) | VAF 72/512 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- DMBT1 | c.6953A>C p.D2318A (on ENST00000338354 / NM_001377530.1; = p.D1561A on NM_004406.3) | Missense Mutation (SNP) | VAF 41/344 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- DMGDH | c.2255C>T p.A752V | Missense Mutation (SNP) | VAF 20/362 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.036); called by muse, mutect2
- DNAH1 | c.4250T>C p.I1417T | Missense Mutation (SNP) | VAF 35/336 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- DNAH17 | c.11903C>T p.A3968V | Missense Mutation (SNP) | VAF 377/509 reads (74%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- DNAJC3 | c.1039G>A p.A347T | Missense Mutation (SNP) | VAF 33/316 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- DND1 | c.670C>T p.L224F | Missense Mutation (SNP) | VAF 36/704 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.026); called by muse, mutect2
- DPF2 | c.1118T>C p.L373P | Missense Mutation (SNP) | VAF 20/482 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DQX1 | c.904C>A p.P302T | Missense Mutation (SNP) | VAF 97/447 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- DSCAM | c.2291A>G p.Y764C | Missense Mutation (SNP) | VAF 90/409 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DSCAML1 | c.4700G>A p.G1567D (on ENST00000321322; = p.G1507D on NM_020693.4) | Missense Mutation (SNP) | VAF 88/668 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- DSP | c.4193T>C p.L1398P | Missense Mutation (SNP) | VAF 34/334 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- DST | c.2240A>T p.E747V (on ENST00000361203 / NM_001374722.1; = p.E421V on NM_001723.6) | Missense Mutation (SNP) | VAF 54/223 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- DUSP6 | c.847del p.R283Gfs*21 | Frame Shift Del (DEL) | VAF 30/293 reads (10%) | called by mutect2, pindel, varscan2
- DXO | c.458C>T p.A153V | Missense Mutation (SNP) | VAF 41/964 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2
- ECHS1 | c.636T>G p.I212M | Missense Mutation (SNP) | VAF 36/335 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.1968G>T p.K656N | Missense Mutation (SNP) | VAF 18/416 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.434); called by muse, mutect2
- EFNB3 | c.287del p.P96Lfs*62 | Frame Shift Del (DEL) | VAF 83/717 reads (12%) | called by mutect2, pindel, varscan2
- EGR4 | c.172G>T p.G58C | Missense Mutation (SNP) | VAF 39/707 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); called by muse, mutect2
- ELAC1 | c.722del p.K241Sfs*23 | Frame Shift Del (DEL) | VAF 60/416 reads (14%) | called by pindel, varscan2
- ELF2 | c.1424A>G p.K475R (on ENST00000379550 / NM_001331036.2; = p.K415R on NM_006874.4) | Missense Mutation (SNP) | VAF 22/636 reads (3%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.549); called by muse, mutect2
- ENPP5 | c.894dup p.E299Rfs*23 | Frame Shift Ins (INS) | VAF 52/524 reads (10%) | called by mutect2, pindel
- EPB41 | c.606del p.K202Nfs*52 (on ENST00000343067 / NM_001166005.2; = p.K202Nfs*35 on NM_203343.3) | Frame Shift Del (DEL) | VAF 35/348 reads (10%) | called by mutect2, pindel, varscan2
- EPM2AIP1 | c.692T>C p.L231P | Missense Mutation (SNP) | VAF 49/515 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2
- EXOSC8 | c.792dup p.L265Tfs*4 | Frame Shift Ins (INS) | VAF 37/337 reads (11%) | called by mutect2, pindel, varscan2
- FAAP100 | c.425C>T p.T142I | Missense Mutation (SNP) | VAF 46/824 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.666); called by muse, mutect2
- FAM171A2 | c.1277C>T p.P426L | Missense Mutation (SNP) | VAF 108/555 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.005); called by muse, varscan2
- FAM234A | c.870G>T p.K290N | Missense Mutation (SNP) | VAF 46/480 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.359); called by muse, mutect2
- FAT2 | c.1168T>C p.F390L | Missense Mutation (SNP) | VAF 16/577 reads (3%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2
- FAT3 | c.2767A>G p.K923E | Missense Mutation (SNP) | VAF 103/456 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- FBLN1 | c.1264T>C p.Y422H | Missense Mutation (SNP) | VAF 21/576 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2
- FBXO11 | c.2086C>A p.L696I (on ENST00000403359 / NM_001190274.2; = p.L612I on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/162 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.916); called by mutect2, varscan2
- FCRL5 | c.982del p.L328* | Frame Shift Del (DEL) | VAF 64/619 reads (10%) | called by mutect2, pindel, varscan2
- FGF23 | c.94C>T p.L32F | Missense Mutation (SNP) | VAF 146/666 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); called by muse, varscan2
- FIBIN | c.460C>T p.Q154* | Nonsense Mutation (SNP) | VAF 64/682 reads (9%) | called by muse, mutect2
- FIZ1 | c.619C>T p.R207W | Missense Mutation (SNP) | VAF 128/408 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); called by muse, varscan2
- FMR1 | c.743C>A p.P248H | Missense Mutation (SNP) | VAF 94/468 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by mutect2, varscan2
- FNDC1 | c.1036T>C p.W346R | Missense Mutation (SNP) | VAF 95/446 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FOXP4 | c.1420T>C p.S474P (on ENST00000307972 / NM_001012426.1; = p.S461P on NM_138457.3) | Missense Mutation (SNP) | VAF 43/451 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- FSHR | c.506G>T p.S169I | Missense Mutation (SNP) | VAF 39/435 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- FYN | c.622C>G p.L208V | Missense Mutation (SNP) | VAF 31/598 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.289); called by muse, mutect2
- GDF7 | c.776del p.G259Afs*10 | Frame Shift Del (DEL) | VAF 122/745 reads (16%) | called by mutect2, pindel, varscan2
- GDNF | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 69/524 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- GFI1 | c.505G>A p.G169S | Missense Mutation (SNP) | VAF 27/668 reads (4%) | SIFT tolerated (0.53); PolyPhen benign (0.014); called by muse, mutect2
- GLB1L3 | c.373T>C p.W125R | Missense Mutation (SNP) | VAF 61/458 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GLI1 | c.2834T>C p.V945A | Missense Mutation (SNP) | VAF 23/690 reads (3%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); called by muse, mutect2
- GLYR1 | c.1158del p.V387Sfs*14 | Frame Shift Del (DEL) | VAF 45/487 reads (9%) | called by mutect2, pindel
- GOLM1 | c.185C>A p.A62D | Missense Mutation (SNP) | VAF 109/581 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GPN3 | c.546del p.A183Qfs*9 | Frame Shift Del (DEL) | VAF 23/244 reads (9%) | called by mutect2, varscan2
- GRIA3 | c.1615A>G p.K539E | Missense Mutation (SNP) | VAF 78/606 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- GRID2IP | c.2744C>A p.A915E | Missense Mutation (SNP) | VAF 250/565 reads (44%) | SIFT tolerated (0.9); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- GRIN2D | c.2049G>T p.Q683H | Missense Mutation (SNP) | VAF 42/367 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GRK6 | c.1646del p.K549Rfs*41 (on ENST00000355472 / NM_001004106.3; = p.K549Rfs*120 on NM_002082.3) | Frame Shift Del (DEL) | VAF 54/510 reads (11%) | called by mutect2, pindel, varscan2
- GSE1 | c.1421T>G p.I474S | Missense Mutation (SNP) | VAF 65/650 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- GSTA2 | c.542T>C p.L181P | Missense Mutation (SNP) | VAF 62/238 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HROB | c.1660del p.S554Lfs*11 | Frame Shift Del (DEL) | VAF 39/367 reads (11%) | called by mutect2, pindel, varscan2
- ICAM5 | c.1886C>A p.P629H | Missense Mutation (SNP) | VAF 73/760 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2
- IFT172 | c.917T>C p.L306P | Missense Mutation (SNP) | VAF 57/251 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IFT46 | c.699T>A p.D233E (on ENST00000264021 / NM_001168618.2; = p.D284E on NM_020153.3) | Missense Mutation (SNP) | VAF 21/577 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.035); called by muse, mutect2
- IFT46 | c.20A>G p.D7G | Missense Mutation (SNP) | VAF 57/469 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- IGHG3 | c.643C>T p.H215Y | Missense Mutation (SNP) | VAF 31/886 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- IGLV8-61 | c.37C>A p.L13I | Missense Mutation (SNP) | VAF 50/492 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.369); called by muse, mutect2
- IL27RA | c.1282G>A p.A428T | Missense Mutation (SNP) | VAF 117/561 reads (21%) | SIFT tolerated (0.65); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- INPP1 | c.1199A>G p.*400Wext*10 | Nonstop Mutation (SNP) | VAF 42/271 reads (15%) | called by muse, mutect2, varscan2
- INTS1 | c.5530A>G p.T1844A | Missense Mutation (SNP) | VAF 30/842 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.021); called by muse, mutect2
- IP6K2 | c.84del p.H29Tfs*56 | Frame Shift Del (DEL) | VAF 103/576 reads (18%) | called by mutect2, varscan2
- IPP | c.905del p.G302Vfs*12 | Frame Shift Del (DEL) | VAF 40/384 reads (10%) | called by mutect2, pindel, varscan2
- IQSEC2 | c.3560del p.P1187Rfs*210 | Frame Shift Del (DEL) | VAF 45/373 reads (12%) | called by mutect2, pindel, varscan2
- IQSEC2 | c.1700G>T p.S567I (on ENST00000642864 / NM_001111125.3; = p.S362I on NM_015075.2) | Missense Mutation (SNP) | VAF 36/1105 reads (3%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.491); called by muse, mutect2
- IRX5 | c.489G>A p.W163* | Nonsense Mutation (SNP) | VAF 91/780 reads (12%) | called by muse, mutect2, varscan2
- ITGA2B | c.1801A>G p.N601D | Missense Mutation (SNP) | VAF 65/543 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- JARID2 | c.3216del p.E1073Kfs*106 | Frame Shift Del (DEL) | VAF 40/402 reads (10%) | called by mutect2, pindel
- KAT14 | c.1453A>T p.T485S | Missense Mutation (SNP) | VAF 170/491 reads (35%) | SIFT tolerated (0.58); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- KAT6A | c.5556G>T p.K1852N | Missense Mutation (SNP) | VAF 56/696 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2
- KCNJ3 | c.257T>C p.I86T | Missense Mutation (SNP) | VAF 53/725 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); called by muse, mutect2
- KCNMA1 | c.2076del p.K692Nfs*15 (on ENST00000286628 / NM_001161352.2; = p.K692Nfs*36 on NM_002247.4) | Frame Shift Del (DEL) | VAF 40/350 reads (11%) | called by mutect2, pindel, varscan2
- KCP | c.1391C>A p.P464H (on ENST00000620378; = p.P521H on NM_001366122.1) | Missense Mutation (SNP) | VAF 75/690 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- KDM7A | c.1034C>T p.T345I | Missense Mutation (SNP) | VAF 14/318 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KIF13A | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 83/373 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- KIF26A | c.864dup p.T289Hfs*174 | Frame Shift Ins (INS) | VAF 102/872 reads (12%) | called by mutect2, pindel, varscan2
- KIFC3 | c.448A>G p.M150V | Missense Mutation (SNP) | VAF 154/687 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- KLHDC1 | c.340A>G p.T114A | Missense Mutation (SNP) | VAF 33/278 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- KMT2D | c.13696G>T p.E4566* | Nonsense Mutation (SNP) | VAF 55/518 reads (11%) | called by muse, mutect2, varscan2
- LAMA2 | c.85C>T p.R29W | Missense Mutation (SNP) | VAF 56/566 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2
- LAMA2 | c.7622C>A p.P2541H | Missense Mutation (SNP) | VAF 51/454 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- LAMB4 | c.2320del p.Q774Rfs*59 | Frame Shift Del (DEL) | VAF 58/423 reads (14%) | called by mutect2, pindel, varscan2
- LENG9 | c.1118del p.P373Lfs*3 | Frame Shift Del (DEL) | VAF 63/642 reads (10%) | called by mutect2, pindel, varscan2
- LMX1B | c.275C>T p.T92I | Missense Mutation (SNP) | VAF 77/581 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- LOXHD1 | c.1270del p.K424Nfs*13 | Frame Shift Del (DEL) | VAF 61/340 reads (18%) | called by mutect2, pindel, varscan2
- LPCAT1 | c.1575del p.R526Gfs*33 | Frame Shift Del (DEL) | VAF 135/681 reads (20%) | called by mutect2, pindel, varscan2
- LRCH4 | c.586A>G p.T196A | Missense Mutation (SNP) | VAF 37/335 reads (11%) | SIFT tolerated (0.88); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- LRIT1 | c.1100G>A p.G367D | Missense Mutation (SNP) | VAF 82/628 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.035); called by muse, mutect2
- LRP6 | c.4172A>G p.Y1391C | Missense Mutation (SNP) | VAF 24/557 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.03); called by muse, mutect2
- LRRC8E | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 90/585 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- LRRC8E | c.1372C>T p.Q458* | Nonsense Mutation (SNP) | VAF 97/739 reads (13%) | called by muse, mutect2, varscan2
- LRRN2 | c.1292del p.P431Qfs*5 | Frame Shift Del (DEL) | VAF 71/619 reads (11%) | called by mutect2, pindel, varscan2
- LRRN2 | c.1174C>T p.P392S | Missense Mutation (SNP) | VAF 31/660 reads (5%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); called by muse, mutect2
- LTB4R | c.30del p.S11Hfs*2 | Frame Shift Del (DEL) | VAF 44/390 reads (11%) | called by mutect2, varscan2
- LTB4R2 | c.793G>A p.G265S (on ENST00000528054; = p.G234S on NM_019839.5) | Missense Mutation (SNP) | VAF 92/786 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- LY6K | c.140A>T p.E47V | Missense Mutation (SNP) | VAF 89/442 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- LYSMD3 | c.306dup p.A103Cfs*3 | Frame Shift Ins (INS) | VAF 28/270 reads (10%) | called by pindel, varscan2
- LYST | c.10101G>T p.K3367N | Missense Mutation (SNP) | VAF 51/469 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MAGEB5 | c.152T>A p.L51Q | Missense Mutation (SNP) | VAF 187/598 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MAGEC1 | c.1265G>A p.S422N | Missense Mutation (SNP) | VAF 64/584 reads (11%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- MAML3 | c.929A>G p.Q310R | Missense Mutation (SNP) | VAF 46/449 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- MAP7D1 | c.1269_1280dup p.N424_E427dup | In Frame Ins (INS) | VAF 94/426 reads (22%) | called by mutect2, varscan2
- MBD6 | c.809del p.P270Lfs*107 | Frame Shift Del (DEL) | VAF 41/439 reads (9%) | called by mutect2, pindel
- MBD6 | c.2792del p.P931Lfs*15 | Frame Shift Del (DEL) | VAF 50/503 reads (10%) | called by mutect2, pindel, varscan2
- MDGA1 | c.1742T>C p.L581P | Missense Mutation (SNP) | VAF 51/1128 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.012); called by muse, mutect2
- MED17 | c.1702G>A p.A568T | Missense Mutation (SNP) | VAF 22/520 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.01); called by muse, mutect2
- MEFV | c.1522del p.L508Cfs*5 | Frame Shift Del (DEL) | VAF 118/577 reads (20%) | called by mutect2, pindel, varscan2
- MGAM | c.722G>T p.S241I | Missense Mutation (SNP) | VAF 128/327 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.383); called by muse, mutect2, varscan2
- MICALL1 | c.832C>T p.P278S | Missense Mutation (SNP) | VAF 65/647 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, varscan2
- MICB | c.305A>G p.H102R | Missense Mutation (SNP) | VAF 66/600 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.968); called by muse, mutect2
- MIOS | c.386T>C p.L129P | Missense Mutation (SNP) | VAF 152/418 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- MRC1 | c.505G>A p.A169T | Missense Mutation (SNP) | VAF 18/550 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0.047); called by muse, mutect2
- MROH2B | c.3959G>T p.R1320M | Missense Mutation (SNP) | VAF 26/660 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- MSRB1 | c.129G>A p.W43* | Nonsense Mutation (SNP) | VAF 49/659 reads (7%) | called by muse, mutect2
- MTCH1 | c.106del p.V36Sfs*57 | Frame Shift Del (DEL) | VAF 93/935 reads (10%) | called by pindel, varscan2
- MUC19 | c.563G>T p.R188I | Missense Mutation (SNP) | VAF 144/394 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- MYB | c.1137G>T p.Q379H | Missense Mutation (SNP) | VAF 125/565 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- MYBPC3 | c.358G>A p.A120T | Missense Mutation (SNP) | VAF 60/579 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYH10 | c.3401G>A p.R1134Q | Missense Mutation (SNP) | VAF 105/495 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, varscan2
- MYO18B | c.1648G>A p.A550T | Missense Mutation (SNP) | VAF 42/512 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.074); called by muse, mutect2
- N4BP3 | c.1290G>T p.Q430H | Missense Mutation (SNP) | VAF 47/723 reads (7%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.972); called by muse, mutect2
- NBPF4 | c.1875G>T p.E625D | Missense Mutation (SNP) | VAF 16/450 reads (4%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.496); called by muse, mutect2
- NFATC2 | c.880T>C p.Y294H | Missense Mutation (SNP) | VAF 23/872 reads (3%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.646); called by muse, mutect2
- NLRP3 | c.673del p.A225Rfs*13 | Frame Shift Del (DEL) | VAF 57/576 reads (10%) | called by mutect2, pindel, varscan2
- NOS2 | c.919del p.L307Wfs*38 | Frame Shift Del (DEL) | VAF 78/648 reads (12%) | called by mutect2, pindel, varscan2
- NPAS2 | c.256A>G p.T86A | Missense Mutation (SNP) | VAF 12/339 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- NPRL3 | c.602C>T p.A201V (on ENST00000611875 / NM_001077350.3; = p.A176V on NM_001039476.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 64/441 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- NR3C1 | c.2108A>C p.K703T | Missense Mutation (SNP) | VAF 44/541 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); called by muse, mutect2
- NUP35 | c.933del p.D312Mfs*26 | Frame Shift Del (DEL) | VAF 39/296 reads (13%) | called by mutect2, pindel, varscan2
- NXF1 | c.1207C>T p.R403* | Nonsense Mutation (SNP) | VAF 98/445 reads (22%) | called by muse, mutect2, varscan2
- NYX | c.361G>A p.G121S | Missense Mutation (SNP) | VAF 181/800 reads (23%) | SIFT tolerated (0.62); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- OBSCN | c.18839C>A p.P6280H | Missense Mutation (SNP) | VAF 30/494 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.005); called by muse, mutect2
- OBSCN | c.21283G>A p.D7095N | Missense Mutation (SNP) | VAF 102/744 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OGT | c.664C>A p.P222T | Missense Mutation (SNP) | VAF 46/492 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); called by muse, mutect2
- OPN5 | c.293G>A p.R98H | Missense Mutation (SNP) | VAF 115/482 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.249); called by muse, mutect2, varscan2
- OR11H2 | c.512C>A p.P171H (on ENST00000556246; = p.P182H on NM_001197287.1) | Missense Mutation (SNP) | VAF 61/976 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- OR5A1 | c.302C>T p.A101V | Missense Mutation (SNP) | VAF 54/500 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.152); called by muse, varscan2
- OTX1 | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 76/937 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0.005); called by muse, mutect2
- OVCH2 | c.449G>T p.G150V | Missense Mutation (SNP) | VAF 45/338 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- P2RY8 | c.259C>T p.H87Y | Missense Mutation (SNP) | VAF 56/1067 reads (5%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2
- PALM2AKAP2 | c.460A>G p.S154G (on ENST00000259318 / NM_001136562.3; = p.S385G on NM_007203.5) | Missense Mutation (SNP) | VAF 32/703 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.13); called by muse, mutect2
- PBRM1 | c.2616dup p.I873Yfs*2 | Frame Shift Ins (INS) | VAF 39/402 reads (10%) | called by mutect2, pindel
- PCDHB10 | c.1057del p.S353Pfs*41 | Frame Shift Del (DEL) | VAF 50/470 reads (11%) | called by mutect2, pindel, varscan2
- PCDHB15 | c.1871T>C p.V624A | Missense Mutation (SNP) | VAF 36/1136 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- PCDHGB5 | c.244G>T p.G82W | Missense Mutation (SNP) | VAF 36/348 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCSK7 | c.1321del p.R441Gfs*33 | Frame Shift Del (DEL) | VAF 72/376 reads (19%) | called by mutect2, pindel, varscan2
- PDCD11 | c.3556A>C p.S1186R | Missense Mutation (SNP) | VAF 39/409 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.391); called by muse, mutect2
- PDIA5 | c.1355C>T p.A452V | Missense Mutation (SNP) | VAF 52/302 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.059); called by muse, varscan2
- PDZD2 | c.3421C>T p.Q1141* | Nonsense Mutation (SNP) | VAF 104/524 reads (20%) | called by muse, varscan2
- PHTF2 | c.1466G>T p.R489I (on ENST00000248550 / NM_001366089.1; = p.R451I on NM_020432.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- PIEZO1 | c.7488G>T p.E2496D | Missense Mutation (SNP) | VAF 65/514 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PIK3CD | c.1444C>T p.P482S | Missense Mutation (SNP) | VAF 23/675 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0.348); called by muse, mutect2
- PIR | c.785A>C p.E262A | Missense Mutation (SNP) | VAF 62/272 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- PJA1 | c.211C>T p.P71S | Missense Mutation (SNP) | VAF 68/862 reads (8%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); called by muse, mutect2
- PKHD1 | c.732G>A p.W244* | Nonsense Mutation (SNP) | VAF 29/601 reads (5%) | called by muse, mutect2
- PKIB | c.139dup p.L47Pfs*17 | Frame Shift Ins (INS) | VAF 94/548 reads (17%) | called by mutect2, pindel, varscan2
- PLCB4 | c.2615del p.N872Mfs*14 | Frame Shift Del (DEL) | VAF 41/429 reads (10%) | called by mutect2, pindel, varscan2
- PLEKHM2 | c.770G>A p.S257N | Missense Mutation (SNP) | VAF 137/621 reads (22%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- PLEKHM2 | c.2432C>T p.T811I | Missense Mutation (SNP) | VAF 44/644 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- PLIN2 | c.220C>T p.P74S | Missense Mutation (SNP) | VAF 33/400 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2
- PLPP5 | c.338+1G>A p.X113_splice | Splice Site (SNP) | VAF 31/433 reads (7%) | called by muse, mutect2
- PNMA8C | c.224C>T p.T75M | Missense Mutation (SNP) | VAF 55/504 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- PODXL | c.703C>A p.L235I | Missense Mutation (SNP) | VAF 20/374 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.026); called by muse, mutect2
- POGK | c.1817C>T p.A606V | Missense Mutation (SNP) | VAF 36/438 reads (8%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.01); called by muse, mutect2
- POLRMT | c.596C>A p.P199H | Missense Mutation (SNP) | VAF 70/716 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- POU4F2 | c.197G>A p.G66D | Missense Mutation (SNP) | VAF 76/610 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.014); called by muse, varscan2
- POU5F2 | c.890G>A p.G297E | Missense Mutation (SNP) | VAF 177/513 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- PPFIA4 | c.1838T>C p.M613T (on ENST00000447715; = p.M614T on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/526 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.101); called by muse, mutect2
- PPP1R16A | c.730T>C p.F244L | Missense Mutation (SNP) | VAF 68/525 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- PPP2R3B | c.1165del p.T389Hfs*70 | Frame Shift Del (DEL) | VAF 69/675 reads (10%) | called by mutect2, pindel
- PPP2R3B | c.41A>G p.K14R | Missense Mutation (SNP) | VAF 69/681 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PPP4R3A | c.727del p.T243Qfs*7 | Frame Shift Del (DEL) | VAF 73/408 reads (18%) | called by mutect2, pindel, varscan2
- PRAG1 | c.2726G>A p.G909D | Missense Mutation (SNP) | VAF 34/772 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.381); called by muse, mutect2
- PRDM8 | c.941G>T p.R314M | Missense Mutation (SNP) | VAF 82/697 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- PRPF4B | c.1819G>A p.V607M | Missense Mutation (SNP) | VAF 19/500 reads (4%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.56); called by muse, mutect2
- PRRC2A | c.5052del p.K1685Rfs*9 | Frame Shift Del (DEL) | VAF 109/865 reads (13%) | called by mutect2, pindel, varscan2
- PRRC2B | c.6233T>C p.M2078T | Missense Mutation (SNP) | VAF 18/436 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.042); called by muse, mutect2
- PRRG1 | c.234G>A p.W78* | Nonsense Mutation (SNP) | VAF 50/516 reads (10%) | called by muse, mutect2
- PRTG | c.1088del p.N363Mfs*19 | Frame Shift Del (DEL) | VAF 66/333 reads (20%) | called by mutect2, pindel, varscan2
- PSD | c.2213del p.G738Afs*12 | Frame Shift Del (DEL) | VAF 67/686 reads (10%) | called by mutect2, pindel, varscan2
- PSMB10 | c.792G>T p.E264D | Missense Mutation (SNP) | VAF 20/530 reads (4%) | SIFT tolerated (0.32); PolyPhen benign (0.021); called by muse, mutect2
- PTCHD1 | c.2414A>G p.Y805C | Missense Mutation (SNP) | VAF 76/654 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- PTPRN | c.2924A>G p.K975R | Missense Mutation (SNP) | VAF 48/485 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.146); called by muse, mutect2
- PXDN | c.2592del p.N865Mfs*25 | Frame Shift Del (DEL) | VAF 86/408 reads (21%) | called by mutect2, pindel, varscan2
- PXDNL | c.2841G>T p.Q947H | Missense Mutation (SNP) | VAF 73/608 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- PYGO1 | c.196C>A p.L66I | Missense Mutation (SNP) | VAF 40/490 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- R3HDM2 | c.897G>T p.R299S | Missense Mutation (SNP) | VAF 20/454 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.166); called by muse, mutect2
- RAB11FIP5 | c.1907G>A p.R636Q | Missense Mutation (SNP) | VAF 40/844 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- RAPH1 | c.2876del p.K959Rfs*42 | Frame Shift Del (DEL) | VAF 47/472 reads (10%) | called by mutect2, varscan2
- RASGRF2 | c.3656T>C p.I1219T | Missense Mutation (SNP) | VAF 28/410 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.054); called by muse, mutect2
- RASSF7 | c.1069G>A p.A357T | Missense Mutation (SNP) | VAF 80/946 reads (8%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.483); called by muse, mutect2
- RBM27 | c.2488del p.R830Dfs*5 | Frame Shift Del (DEL) | VAF 29/205 reads (14%) | called by mutect2, pindel, varscan2
- RBM47 | c.202C>T p.Q68* | Nonsense Mutation (SNP) | VAF 113/853 reads (13%) | called by muse, mutect2, varscan2
- REV1 | c.1019C>A p.P340Q | Missense Mutation (SNP) | VAF 44/550 reads (8%) | SIFT tolerated (0.58); PolyPhen benign (0.062); called by muse, mutect2
- REXO1 | c.1783del p.A595Rfs*58 | Frame Shift Del (DEL) | VAF 42/395 reads (11%) | called by mutect2, pindel
- RFWD3 | c.515C>T p.A172V | Missense Mutation (SNP) | VAF 62/252 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- RIMBP2 | c.1223A>G p.Q408R | Missense Mutation (SNP) | VAF 94/662 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- RIPK3 | c.1258G>T p.G420* | Nonsense Mutation (SNP) | VAF 71/388 reads (18%) | called by muse, mutect2, varscan2
- RNF25 | c.95A>G p.Q32R | Missense Mutation (SNP) | VAF 24/436 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.012); called by muse, mutect2
- RNF39 | c.66dup p.R23Afs*7 | Frame Shift Ins (INS) | VAF 94/1062 reads (9%) | called by mutect2, pindel
- RPS6KA5 | c.1874A>G p.H625R | Missense Mutation (SNP) | VAF 44/395 reads (11%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- RRNAD1 | c.1095del p.R366Gfs*20 | Frame Shift Del (DEL) | VAF 60/537 reads (11%) | called by mutect2, pindel, varscan2
- RSPH3 | c.560A>G p.H187R (on ENST00000252655; = p.H45R on NM_031924.8) | Missense Mutation (SNP) | VAF 20/305 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- RTTN | c.5251C>A p.L1751M | Missense Mutation (SNP) | VAF 24/532 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.273); called by muse, mutect2
- RXRB | c.668A>G p.E223G | Missense Mutation (SNP) | VAF 62/662 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2
- SAMD1 | c.1192G>T p.G398C | Missense Mutation (SNP) | VAF 51/579 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SATB2 | c.315dup p.Y106Vfs*103 | Frame Shift Ins (INS) | VAF 77/493 reads (16%) | called by mutect2, pindel, varscan2
- SCN8A | c.5426C>T p.A1809V | Missense Mutation (SNP) | VAF 62/633 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.045); called by muse, mutect2
- SCYL1 | c.119G>A p.G40D | Missense Mutation (SNP) | VAF 21/361 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.599); called by muse, mutect2
- SCYL2 | c.2179_2180del p.M727Vfs*9 | Frame Shift Del (DEL) | VAF 38/334 reads (11%) | called by pindel, varscan2
- SERPINA2 | c.772C>T p.R258W | Missense Mutation (SNP) | VAF 109/535 reads (20%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- SESTD1 | c.2024G>T p.R675M | Missense Mutation (SNP) | VAF 42/470 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.299); called by muse, mutect2
- SEZ6L | c.386G>T p.R129M | Missense Mutation (SNP) | VAF 27/703 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.533); called by muse, mutect2
- SGTA | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 25/472 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); called by muse, mutect2
- SHPRH | c.3638del p.N1213Tfs*60 (on ENST00000275233 / NM_001042683.3; = p.N1217Tfs*60 on NM_173082.3) | Frame Shift Del (DEL) | VAF 56/469 reads (12%) | called by mutect2, pindel, varscan2
- SIPA1 | c.2283del p.D762Tfs*37 | Frame Shift Del (DEL) | VAF 64/540 reads (12%) | called by mutect2, varscan2
- SKIV2L | c.502A>G p.N168D | Missense Mutation (SNP) | VAF 25/705 reads (4%) | SIFT tolerated (0.64); PolyPhen benign (0.003); called by muse, mutect2
- SKOR1 | c.281G>A p.G94D | Missense Mutation (SNP) | VAF 26/824 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2
- SKOR1 | c.1094G>A p.G365D | Missense Mutation (SNP) | VAF 90/852 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- SLC12A8 | c.1432A>G p.R478G | Missense Mutation (SNP) | VAF 59/511 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLC18A3 | c.998C>T p.P333L | Missense Mutation (SNP) | VAF 40/934 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC19A1 | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 79/645 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- SLC1A2 | c.611A>C p.E204A | Missense Mutation (SNP) | VAF 44/462 reads (10%) | SIFT tolerated (0.58); PolyPhen benign (0.005); called by muse, mutect2
- SLC1A7 | c.364_366del p.K122del | In Frame Del (DEL) | VAF 59/712 reads (8%) | called by mutect2, pindel
- SLC20A2 | c.1175C>T p.A392V | Missense Mutation (SNP) | VAF 25/550 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.941); called by muse, mutect2
- SLC22A31 | c.946del p.R316Afs*44 | Frame Shift Del (DEL) | VAF 86/879 reads (10%) | called by mutect2, pindel, varscan2
- SLC25A34 | c.484G>T p.G162W | Missense Mutation (SNP) | VAF 34/768 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC38A6 | c.104del p.N35Tfs*20 | Frame Shift Del (DEL) | VAF 33/307 reads (11%) | called by mutect2, pindel, varscan2
- SLC39A3 | c.44T>C p.V15A | Missense Mutation (SNP) | VAF 93/464 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- SLC39A4 | c.321del p.E108Rfs*29 (on ENST00000301305 / NM_001374839.1; = p.E83Rfs*29 on NM_017767.3) | Frame Shift Del (DEL) | VAF 99/938 reads (11%) | called by mutect2, pindel, varscan2
- SLC45A4 | c.316G>A p.G106R (on ENST00000517878 / NM_001286646.2; = p.G55R on NM_001080431.2) | Missense Mutation (SNP) | VAF 224/636 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, varscan2
- SLC9C1 | c.817G>A p.V273M | Missense Mutation (SNP) | VAF 35/370 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2
- SND1 | c.2168del p.P723Lfs*2 | Frame Shift Del (DEL) | VAF 75/605 reads (12%) | called by mutect2, varscan2
- SNRPD2 | c.220T>C p.W74R | Missense Mutation (SNP) | VAF 103/474 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); called by muse, varscan2
- SNX16 | c.553C>T p.Q185* | Nonsense Mutation (SNP) | VAF 15/372 reads (4%) | called by muse, mutect2
- SORBS2 | c.941T>C p.I314T | Missense Mutation (SNP) | VAF 40/429 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2
- SOWAHC | c.426del p.A143Rfs*6 | Frame Shift Del (DEL) | VAF 107/798 reads (13%) | called by mutect2, pindel, varscan2
- SPAM1 | c.256C>T p.Q86* | Nonsense Mutation (SNP) | VAF 58/509 reads (11%) | called by muse, mutect2, varscan2
- SPRYD3 | c.586C>T p.R196W | Missense Mutation (SNP) | VAF 73/560 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.668); called by muse, mutect2, varscan2
- SRCAP | c.176G>A p.G59E | Missense Mutation (SNP) | VAF 125/697 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- SRCIN1 | c.3113C>A p.P1038H (on ENST00000621492; = p.P1004H on NM_025248.3) | Missense Mutation (SNP) | VAF 71/546 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SRCIN1 | c.45del p.M16Cfs*44 | Frame Shift Del (DEL) | VAF 143/601 reads (24%) | called by mutect2, pindel, varscan2
- STARD9 | c.7273C>G p.P2425A | Missense Mutation (SNP) | VAF 25/541 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.175); called by muse, mutect2
- STAT1 | c.1601_1603dup p.D534dup | In Frame Ins (INS) | VAF 114/408 reads (28%) | called by mutect2, pindel, varscan2
- STIM2 | c.1762T>C p.W588R | Missense Mutation (SNP) | VAF 26/265 reads (10%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- STK19 | c.589del p.E197Rfs*47 (on ENST00000375333 / NM_032454.1; = p.E197Rfs*43 on NM_004197.1) | Frame Shift Del (DEL) | VAF 64/544 reads (12%) | called by mutect2, pindel, varscan2
- STK38L | c.309G>T p.E103D | Missense Mutation (SNP) | VAF 23/192 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- STX2 | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 62/534 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- SULF2 | c.2463G>T p.Q821H | Missense Mutation (SNP) | VAF 47/499 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); called by muse, mutect2
- SUPV3L1 | c.533A>G p.D178G | Missense Mutation (SNP) | VAF 16/369 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- SVIL | c.5956G>A p.A1986T (on ENST00000355867 / NM_021738.3; = p.A1560T on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/467 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.082); called by muse, mutect2
- SYN3 | c.1211C>T p.P404L | Missense Mutation (SNP) | VAF 22/517 reads (4%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.879); called by muse, mutect2
- SYNGAP1 | c.596A>G p.N199S | Missense Mutation (SNP) | VAF 45/856 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.045); called by muse, mutect2
- SYNGR1 | c.195del p.N66Tfs*75 | Frame Shift Del (DEL) | VAF 81/756 reads (11%) | called by mutect2, pindel, varscan2
- SYP | c.733G>A p.A245T | Missense Mutation (SNP) | VAF 98/965 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
379 further variants in this file (81 protein-altering or splice-affecting, 259 silent, 39 other) are not listed here.
